Somatic mutation profile of tumor specimen 9899e1ad-62e1-4cc2-91fc-49b85c (aliquot 9899e1ad-62e1-4cc2-91fc-49b85c_D6) from CPTAC case 05CO007, project CPTAC-2 (Colon — Adenomas and Adenocarcinomas). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIC.
Specimen 9899e1ad-62e1-4cc2-91fc-49b85c: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 58907658-618f-4380-9121-2bd8ac760b3e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 6539f675-8d03-49eb-abc4-65f803 (Blood Derived Normal), aliquot 6539f675-8d03-49eb-abc4-65f803_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/585ce7b6-47ce-4a72-aa6f-6a5676e56f81

The open-access MAF lists 1,230 somatic variants for this specimen: 837 protein-altering or splice-affecting, 247 silent, 146 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 598, Silent 247, Frame Shift Del 144, Intron 86, Nonsense Mutation 31, Frame Shift Ins 30, 3'UTR 25, Splice Region 18, Splice Site 12, RNA 12, 5'UTR 8, 3'Flank 8.

Variants (750 of 1,230; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AP002748.5 | c.1396dup p.R466Pfs*72 | Frame Shift Ins (INS) | VAF 81/546 reads (15%) | catalogued as rs1565287921; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ARID1A | c.4381C>T p.R1461* | Nonsense Mutation (SNP) | VAF 74/453 reads (16%) | hotspot (GDC flag); catalogued as COSV61376088; called by muse, mutect2, varscan2
- ATP8B1 | c.614dup p.N205Kfs*2 | Frame Shift Ins (INS) | VAF 34/263 reads (13%) | catalogued as rs761784230; ClinVar: pathogenic; called by mutect2, varscan2
- B2M | c.68-2A>C p.X23_splice | Splice Site (SNP) | VAF 24/338 reads (7%) | hotspot (GDC flag); catalogued as COSV62562974, COSV62564351; called by muse, mutect2
- BRCA2 | c.5583del p.V1862* | Frame Shift Del (DEL) | VAF 9/76 reads (12%) | catalogued as rs397507790, COSV66450671; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- CHD7 | c.4480C>T p.R1494* | Nonsense Mutation (SNP) | VAF 21/189 reads (11%) | catalogued as rs587783442, CM066002; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FMO3 | c.154G>A p.A52T | Missense Mutation (SNP) | VAF 87/439 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.26); catalogued as rs72549321, CM992883; ClinVar: pathogenic; called by muse, mutect2, varscan2
- OPLAH | c.2608del p.H870Tfs*28 | Frame Shift Del (DEL) | VAF 27/251 reads (11%) | catalogued as rs781956288; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TFR2 | c.313C>T p.R105* | Nonsense Mutation (SNP) | VAF 56/331 reads (17%) | catalogued as rs80338878, CM042497; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ZNF469 | c.10248del p.R3417Gfs*56 (on ENST00000437464; = p.R3445Gfs*56 on NM_001367624.2) | Frame Shift Del (DEL) | VAF 50/262 reads (19%) | catalogued as rs764470052, COSV99081573; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- ABCC10 | c.1066C>T p.R356W (on ENST00000372530 / NM_001198934.2; = p.R313W on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/307 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs150694420; called by muse, mutect2, varscan2
- ABCE1 | c.1263+11_1263+13del | Splice Region (DEL) | VAF 21/121 reads (17%) | catalogued as rs768287999; called by pindel, varscan2
- ABCG1 | c.211C>T p.R71W | Missense Mutation (SNP) | VAF 44/370 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs768010170; called by muse, mutect2, varscan2
- AC053503.6 | c.460C>T p.R154C | Missense Mutation (SNP) | VAF 8/164 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as rs1446297980; called by muse, mutect2
- ACVR1B | c.1420C>T p.R474* | Nonsense Mutation (SNP) | VAF 23/191 reads (12%) | catalogued as rs906303606, COSV57776895; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 22/92 reads (24%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAMTSL1 | c.2998G>A p.G1000R | Missense Mutation (SNP) | VAF 47/277 reads (17%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.539); catalogued as COSV65896571; called by muse, mutect2, varscan2
- ADAMTSL1 | c.4522dup p.V1508Gfs*80 | Frame Shift Ins (INS) | VAF 44/301 reads (15%) | catalogued as rs777337513; called by mutect2, pindel, varscan2
- ADGRB2 | c.253C>T p.R85C | Missense Mutation (SNP) | VAF 37/228 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.416); catalogued as rs1273238867; called by muse, mutect2, varscan2
- AFAP1L1 | c.2123G>T p.G708V | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99696189; called by mutect2, varscan2
- AGL | c.2918G>A p.R973Q | Missense Mutation (SNP) | VAF 100/575 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1012435007, COSV54049485; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AHNAK2 | c.17300C>T p.A5767V | Missense Mutation (SNP) | VAF 32/207 reads (15%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as rs762670485, COSV60922883; called by muse, mutect2, varscan2
- AIFM3 | c.70C>T p.R24* | Nonsense Mutation (SNP) | VAF 58/361 reads (16%) | catalogued as rs569194029; called by muse, mutect2, varscan2
- AK1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 84/463 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1338494405; called by muse, mutect2, varscan2
- ALK | c.3542G>A p.R1181H | Missense Mutation (SNP) | VAF 67/500 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.38); catalogued as rs1034835558, COSV66565306; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALPK2 | c.1067del p.L356Yfs*2 | Frame Shift Del (DEL) | VAF 24/210 reads (11%) | catalogued as rs756508755; called by mutect2, pindel
- ALPK3 | c.3707G>A p.G1236E | Missense Mutation (SNP) | VAF 28/164 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as rs1254967575; called by muse, mutect2, varscan2
- AMOT | c.1882C>T p.R628W (on ENST00000371959 / NM_001113490.1; = p.R219W on NM_133265.3) | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776380270; called by mutect2, varscan2
- ANK2 | c.10367dup p.T3457Hfs*8 | Frame Shift Ins (INS) | VAF 88/282 reads (31%) | catalogued as rs750143580; called by mutect2, varscan2
- ANKFN1 | c.395C>T p.S132L | Missense Mutation (SNP) | VAF 17/117 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.206); catalogued as rs199650832, COSV100593159; called by muse, mutect2, varscan2
- ANKRD30B | c.1642G>T p.E548* | Nonsense Mutation (SNP) | VAF 15/105 reads (14%) | catalogued as COSV62814641; called by muse, mutect2, varscan2
- ANKRD36 | c.205C>A p.L69I | Missense Mutation (SNP) | VAF 22/195 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV101347533; called by muse, mutect2, varscan2
- ANO3 | c.2940G>A p.W980* | Nonsense Mutation (SNP) | VAF 10/155 reads (6%) | catalogued as COSV56791806; called by muse, mutect2
- ARHGEF10 | c.3962G>A p.R1321H (on ENST00000398564; = p.R1296H on NM_014629.4) | Missense Mutation (SNP) | VAF 109/444 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs771239988; called by muse, mutect2, varscan2
- ARHGEF10L | c.3110G>A p.R1037H | Missense Mutation (SNP) | VAF 36/150 reads (24%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.633); catalogued as rs760033554, COSV51430427; called by muse, mutect2, varscan2
- ARHGEF17 | c.2123G>A p.R708Q | Missense Mutation (SNP) | VAF 37/226 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs1362817814; called by muse, mutect2, varscan2
- ARHGEF2 | c.1565C>T p.S522L (on ENST00000361247 / NM_001162383.2; = p.S494L on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs756219943, COSV58106853; called by muse, mutect2, varscan2
- ASAP1 | c.2663C>T p.A888V | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.112); catalogued as rs374657898; called by mutect2, varscan2
- ASB17 | c.530del p.N177Tfs*7 | Frame Shift Del (DEL) | VAF 66/389 reads (17%) | catalogued as rs749460467; called by mutect2, pindel, varscan2
- ASTN1 | c.1805G>A p.R602H | Missense Mutation (SNP) | VAF 29/164 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs375093597; called by muse, mutect2, varscan2
- ATP13A1 | c.2750G>A p.R917Q | Missense Mutation (SNP) | VAF 40/189 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.031); catalogued as rs554029391, COSV52284206; called by muse, mutect2, varscan2
- ATP4B | c.428G>A p.R143H | Missense Mutation (SNP) | VAF 30/346 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs754901792, COSV100089976; called by muse, mutect2
- ATP7B | c.1543+1G>C p.X515_splice | Splice Site (SNP) | VAF 57/412 reads (14%) | catalogued as rs1360279134, CS040832, CS982085; called by muse, mutect2, varscan2
- B3GNT2 | c.251C>T p.A84V | Missense Mutation (SNP) | VAF 17/142 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs139589693; called by muse, mutect2, varscan2
- B4GALT2 | c.989C>T p.T330M | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV58846358; called by muse, mutect2, varscan2
- BARHL2 | c.376del p.Q126Sfs*18 | Frame Shift Del (DEL) | VAF 13/84 reads (15%) | catalogued as rs747119215; called by mutect2, pindel, varscan2
- BCAR1 | c.1100del p.P367Rfs*104 | Frame Shift Del (DEL) | VAF 18/95 reads (19%) | catalogued as rs1456919135; called by mutect2, pindel, varscan2
- BEST3 | c.1525G>A p.E509K | Missense Mutation (SNP) | VAF 56/367 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); catalogued as rs759773937, COSV58303887; called by muse, mutect2, varscan2
- BICRA | c.3922C>T p.L1308F | Missense Mutation (SNP) | VAF 40/292 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.04); catalogued as rs1241599035; called by muse, mutect2, varscan2
- BMP1 | c.680G>A p.R227Q | Missense Mutation (SNP) | VAF 30/280 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1357286507, COSV60480067; called by muse, mutect2, varscan2
- BORCS5 | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 53/296 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs751586979, COSV53802707, COSV53804547; called by muse, mutect2, varscan2
- BRAT1 | c.1340C>T p.T447M | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.053); catalogued as rs368808380; ClinVar: uncertain significance; called by mutect2, varscan2
- BSG | c.706del p.E236Rfs*32 | Frame Shift Del (DEL) | VAF 50/251 reads (20%) | catalogued as COSV99048680; called by mutect2, pindel, varscan2
- C12orf42 | c.1058C>T p.P353L | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.049); catalogued as rs762594015; called by muse, mutect2, varscan2
- CACNA1A | c.2270C>T p.A757V | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs200355966; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CALML5 | c.371G>A p.R124H | Missense Mutation (SNP) | VAF 48/266 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.878); catalogued as rs747259829; called by muse, mutect2, varscan2
- CARF | c.675_678del p.S226Rfs*4 | Frame Shift Del (DEL) | VAF 8/76 reads (11%) | catalogued as rs753767587; called by mutect2, pindel
- CASD1 | c.1634-1G>T p.X545_splice | Splice Site (SNP) | VAF 20/114 reads (18%) | catalogued as COSV51970807; called by mutect2, varscan2
- CASS4 | c.334G>A p.V112I | Missense Mutation (SNP) | VAF 18/138 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs761524521; called by muse, mutect2, varscan2
- CBX5 | c.317del p.K106Rfs*31 | Frame Shift Del (DEL) | VAF 7/29 reads (24%) | catalogued as rs780649799; called by mutect2, varscan2
- CCDC102A | c.1135C>T p.R379W | Missense Mutation (SNP) | VAF 62/430 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs761275903; called by muse, mutect2, varscan2
- CCDC114 | c.1711C>T p.H571Y | Missense Mutation (SNP) | VAF 28/327 reads (9%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs201978305; ClinVar: uncertain significance; called by muse, mutect2
- CCDC151 | c.949C>T p.R317C | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.097); catalogued as rs1362360086, COSV62698649; called by muse, mutect2
- CCDC157 | c.1160G>A p.R387H | Missense Mutation (SNP) | VAF 37/197 reads (19%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs745435347; called by muse, mutect2, varscan2
- CCDC181 | c.1265del p.K422Sfs*6 (on ENST00000367806 / NM_001300969.1; = p.K421Sfs*6 on NM_021179.2) | Frame Shift Del (DEL) | VAF 10/60 reads (17%) | catalogued as rs759258977; called by mutect2, varscan2
- CCDC73 | c.3192del p.R1066Efs*13 | Frame Shift Del (DEL) | VAF 16/111 reads (14%) | catalogued as rs1356986265, COSV58794814; called by mutect2, pindel, varscan2
- CDH18 | c.1459G>A p.E487K | Missense Mutation (SNP) | VAF 19/155 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.035); catalogued as rs370630427; called by muse, mutect2, varscan2
- CDH22 | c.2041G>A p.E681K | Missense Mutation (SNP) | VAF 32/163 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.727); catalogued as rs1478823542; called by muse, mutect2, varscan2
- CDK2 | c.410C>T p.T137I | Missense Mutation (SNP) | VAF 35/188 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.083); catalogued as rs1449200295; called by muse, mutect2, varscan2
- CDK3 | c.650G>A p.R217H | Missense Mutation (SNP) | VAF 54/320 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.234); catalogued as rs1296582663; called by muse, mutect2, varscan2
- CDK5R2 | c.341G>A p.G114D | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as COSV56935990; called by muse, mutect2, varscan2
- CDKL5 | c.1526C>T p.A509V | Missense Mutation (SNP) | VAF 43/212 reads (20%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.017); catalogued as rs779325312; ClinVar: likely benign; called by muse, mutect2, varscan2
- CDT1 | c.1510G>A p.E504K | Missense Mutation (SNP) | VAF 82/516 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as rs548414653, COSV99967386; called by muse, mutect2, varscan2
- CEP104 | c.103C>T p.R35W | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764366578, COSV58215086; called by muse, mutect2, varscan2
- CFAP69 | c.2061del p.K687Nfs*43 | Frame Shift Del (DEL) | VAF 10/52 reads (19%) | catalogued as rs1275710203; called by mutect2, pindel
- CFAP92 | c.1438G>A p.V480I | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.047); catalogued as rs772329142; called by muse, mutect2
- CHD5 | c.3125G>A p.R1042H | Missense Mutation (SNP) | VAF 15/193 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52417318; called by muse, mutect2
- CIPC | c.802G>A p.A268T | Missense Mutation (SNP) | VAF 56/340 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.02); catalogued as rs773785918, COSV62376759; called by muse, mutect2, varscan2
- CKAP2 | c.1817del p.K606Rfs*14 (on ENST00000378037 / NM_001098525.2; = p.K605Rfs*14 on NM_018204.5) | Frame Shift Del (DEL) | VAF 32/268 reads (12%) | catalogued as rs752250702; called by mutect2, varscan2
- CKLF | c.389G>A p.R130Q (on ENST00000264001 / NM_016951.4; = p.R45Q on NM_016326.3) | Missense Mutation (SNP) | VAF 38/222 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.142); catalogued as rs536256590; called by muse, mutect2, varscan2
- CLIP2 | c.323G>A p.W108* | Nonsense Mutation (SNP) | VAF 38/279 reads (14%) | catalogued as rs1554732642; called by muse, mutect2, varscan2
- CMBL | c.97T>C p.Y33H | Missense Mutation (SNP) | VAF 72/435 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56983069; called by muse, mutect2, varscan2
- CNNM4 | c.1796G>A p.R599H | Missense Mutation (SNP) | VAF 92/716 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs374698559; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CNTNAP2 | c.1999G>A p.A667T | Missense Mutation (SNP) | VAF 80/501 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.059); catalogued as rs374920791; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CNTNAP5 | c.247G>A p.G83R | Missense Mutation (SNP) | VAF 9/125 reads (7%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.881); catalogued as rs1301592326, COSV70472897; called by muse, mutect2
- COL6A3 | c.6917G>A p.R2306H | Missense Mutation (SNP) | VAF 35/269 reads (13%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.952); catalogued as rs1177122610; called by muse, mutect2, varscan2
- CPAMD8 | c.4705C>T p.P1569S (on ENST00000651564; = p.P1522S on NM_015692.5) | Missense Mutation (SNP) | VAF 28/172 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as rs374079295; called by muse, mutect2, varscan2
- CPT1B | c.1745G>T p.R582M | Missense Mutation (SNP) | VAF 26/199 reads (13%) | SIFT tolerated (0.54); PolyPhen benign (0.038); catalogued as COSV56415291; called by muse, mutect2, varscan2
- CRLF3 | c.902C>T p.S301L | Missense Mutation (SNP) | VAF 21/159 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as rs200175473, COSV60836014; called by muse, mutect2, varscan2
- CRYBG2 | c.1178del p.K393Rfs*16 | Frame Shift Del (DEL) | VAF 12/80 reads (15%) | catalogued as rs747248693; called by mutect2, varscan2
- CSGALNACT1 | c.338dup p.E114Rfs*37 | Frame Shift Ins (INS) | VAF 100/787 reads (13%) | catalogued as rs1429340974; called by mutect2, pindel, varscan2
- CSRNP2 | c.212T>C p.V71A | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57333902; called by muse, mutect2, varscan2
- CTNND2 | c.2236G>A p.V746M | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs968695651, COSV58926447; called by muse, mutect2
- CX3CR1 | c.734C>T p.T245I | Missense Mutation (SNP) | VAF 46/293 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.757); catalogued as rs780062312; called by muse, mutect2, varscan2
- CXXC5 | c.808C>T p.R270W | Missense Mutation (SNP) | VAF 46/216 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs755174634, COSV56793253; called by muse, mutect2, varscan2
- CYFIP2 | c.1219G>A p.V407I | Missense Mutation (SNP) | VAF 27/171 reads (16%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.699); catalogued as rs747579286; called by muse, mutect2, varscan2
- DAB2IP | c.3073del p.H1025Tfs*5 (on ENST00000408936; = p.H997Tfs*5 on NM_032552.3) | Frame Shift Del (DEL) | VAF 28/110 reads (25%) | catalogued as rs751187768; called by mutect2, varscan2
- DCHS2 | c.1702G>A p.E568K | Missense Mutation (SNP) | VAF 48/286 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.124); catalogued as rs1000724585, COSV59719574; called by muse, mutect2, varscan2
- DDX24 | c.1765C>T p.R589C | Missense Mutation (SNP) | VAF 49/307 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1194250450, COSV58213845; called by muse, mutect2, varscan2
- DDX27 | c.2072del p.K691Rfs*4 | Frame Shift Del (DEL) | VAF 18/82 reads (22%) | catalogued as rs766714372; called by mutect2, varscan2
- DENND2B | c.3208C>T p.R1070C | Missense Mutation (SNP) | VAF 47/286 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs375990683; called by muse, mutect2, varscan2
- DNAH1 | c.5639C>T p.T1880M | Missense Mutation (SNP) | VAF 25/150 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1191126652, COSV101324962; called by muse, mutect2, varscan2
- DNAH12 | c.3069dup p.C1024Mfs*3 (on ENST00000351747; = p.C1047Mfs*3 on NM_001366028.2) | Frame Shift Ins (INS) | VAF 33/170 reads (19%) | catalogued as rs938145698; called by mutect2, varscan2
- DNAI4 | c.89del p.K30Rfs*28 | Frame Shift Del (DEL) | VAF 22/182 reads (12%) | catalogued as rs774662919; called by mutect2, pindel, varscan2
- DNAJC22 | c.823C>T p.R275C | Missense Mutation (SNP) | VAF 37/191 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.332); catalogued as rs200327446, COSV101222508; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 16/92 reads (17%) | catalogued as rs782552436; called by mutect2, varscan2
- DPF2 | c.184C>T p.R62W | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52887890; called by muse, mutect2, varscan2
- DTHD1 | c.653_656del p.V218Afs*4 (on ENST00000456874; = p.V53Afs*4 on NM_001136536.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 44/390 reads (11%) | catalogued as rs1440209090; called by pindel, varscan2
- EFCAB6 | c.4489C>T p.R1497W | Missense Mutation (SNP) | VAF 34/192 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs200755477; called by muse, mutect2, varscan2
- EFEMP2 | c.1306G>A p.V436I | Missense Mutation (SNP) | VAF 84/527 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs774228818; called by muse, mutect2, varscan2
- EGLN2 | c.793C>T p.R265C | Missense Mutation (SNP) | VAF 42/244 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.584); catalogued as rs377663762; called by muse, mutect2, varscan2
- EIF4G3 | c.1689dup p.V564Sfs*12 | Frame Shift Ins (INS) | VAF 46/245 reads (19%) | catalogued as rs1558140642; called by mutect2, varscan2
- EIF5B | c.2008G>A p.A670T | Missense Mutation (SNP) | VAF 11/117 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs905201172; called by muse, mutect2, varscan2
- EPB42 | c.901C>T p.R301C (on ENST00000441366 / NM_001114134.2; = p.R331C on NM_000119.3) | Missense Mutation (SNP) | VAF 36/572 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.759); catalogued as rs886051167, COSV55751284; ClinVar: uncertain significance; called by muse, mutect2
- EQTN | c.77-3del | Splice Region (DEL) | VAF 12/88 reads (14%) | catalogued as rs768793415; called by mutect2, varscan2
- ERMP1 | c.1305del p.K435Nfs*24 | Frame Shift Del (DEL) | VAF 9/94 reads (10%) | catalogued as rs1209777880; called by mutect2, pindel, varscan2
- ERN2 | c.1396C>A p.P466T | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.051); catalogued as rs1234592809; called by muse, mutect2, varscan2
- ESPL1 | c.433C>T p.R145W | Missense Mutation (SNP) | VAF 25/251 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as rs1219945142, COSV57758846; called by muse, mutect2
- ETS2 | c.286C>T p.R96C | Missense Mutation (SNP) | VAF 20/210 reads (10%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.913); catalogued as rs930149085; called by muse, mutect2
- EVC2 | c.2195C>T p.A732V | Missense Mutation (SNP) | VAF 51/775 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1479577183; called by muse, mutect2
- F13B | c.1313G>A p.R438H | Missense Mutation (SNP) | VAF 71/368 reads (19%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as rs192220037, COSV66374039; called by muse, mutect2, varscan2
- FAAP100 | c.1404-4G>A | Splice Region (SNP) | VAF 29/187 reads (16%) | catalogued as rs376849624; called by muse, mutect2, varscan2
- FADS2 | c.736C>T p.P246S | Missense Mutation (SNP) | VAF 22/224 reads (10%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.979); catalogued as COSV99609270; called by muse, mutect2
- FADS3 | c.916C>T p.R306C | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1047862448, COSV53879340; called by muse, mutect2, varscan2
- FAM117A | c.553G>A p.A185T | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.03); catalogued as rs749711689, COSV53632675; called by muse, mutect2, varscan2
- FAM135B | c.3049G>A p.A1017T | Missense Mutation (SNP) | VAF 35/246 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99422721; called by muse, mutect2, varscan2
- FAM13A | c.2466+1G>A p.X822_splice | Splice Site (SNP) | VAF 13/106 reads (12%) | catalogued as rs1321683594; called by muse, varscan2
- FAM207A | c.658C>T p.R220W | Missense Mutation (SNP) | VAF 47/318 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.627); catalogued as rs749820645; called by muse, mutect2, varscan2
- FAM83G | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 24/182 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1006232643; called by muse, mutect2, varscan2
- FAM83H | c.2869G>A p.G957S | Missense Mutation (SNP) | VAF 73/488 reads (15%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.731); catalogued as rs1554621918; called by muse, mutect2, varscan2
- FBXL8 | c.1090G>A p.E364K | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.481); catalogued as rs147591659, COSV50456591; ClinVar: benign; called by muse, mutect2, varscan2
- FCHO1 | c.1591C>T p.P531S | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.047); catalogued as rs1206570762; called by muse, mutect2, varscan2
- FEM1C | c.1539A>G p.I513M | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.292); catalogued as rs201100876; called by mutect2, varscan2
- FGD5 | c.3239G>A p.R1080H | Missense Mutation (SNP) | VAF 59/347 reads (17%) | SIFT tolerated (0.57); PolyPhen benign (0.062); catalogued as rs375051384; called by muse, mutect2, varscan2
- FHAD1 | c.2388G>A p.E796= | Splice Region (SNP) | VAF 14/110 reads (13%) | catalogued as COSV58989537; called by muse, mutect2, varscan2
- FILIP1 | c.3116T>C p.V1039A | Missense Mutation (SNP) | VAF 38/243 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as COSV99383946; called by muse, mutect2, varscan2
- FLT4 | c.89del p.P30Rfs*3 | Frame Shift Del (DEL) | VAF 62/376 reads (16%) | catalogued as COSV56098414; called by mutect2, pindel, varscan2
- FNDC1 | c.1357G>A p.A453T | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as rs762540669, COSV51942450; called by muse, mutect2, varscan2
- FNDC3B | c.2231G>T p.R744M | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61042926; called by muse, mutect2
- FTO | c.308G>A p.G103D | Missense Mutation (SNP) | VAF 19/396 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1203776934; called by muse, mutect2
- FUBP3 | c.733G>A p.G245S | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as rs535759409; called by muse, mutect2, varscan2
- FXR1 | c.371del p.N124Ifs*14 | Frame Shift Del (DEL) | VAF 13/78 reads (17%) | catalogued as rs756304971; called by mutect2, varscan2
- GAL | c.16G>T p.A6S | Missense Mutation (SNP) | VAF 27/158 reads (17%) | SIFT tolerated (0.5); PolyPhen benign (0.025); catalogued as COSV55764134; called by muse, mutect2, varscan2
- GALNT14 | c.134C>T p.S45L | Missense Mutation (SNP) | VAF 14/149 reads (9%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs867404786, COSV61103210; called by muse, mutect2, varscan2
- GAS2L1 | c.1757C>T p.T586M | Missense Mutation (SNP) | VAF 48/339 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs775867065; called by muse, mutect2, varscan2
- GATM | c.844C>T p.R282C | Missense Mutation (SNP) | VAF 39/291 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs766583032, COSV67540177; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GCC1 | c.1985G>A p.R662H | Missense Mutation (SNP) | VAF 27/161 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs776237823, COSV100365703, COSV58462562; called by muse, mutect2, varscan2
- GDF10 | c.973C>T p.P325S | Missense Mutation (SNP) | VAF 42/333 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs782144559; called by muse, mutect2, varscan2
- GEMIN5 | c.2176del p.S726Vfs*24 | Frame Shift Del (DEL) | VAF 32/214 reads (15%) | catalogued as COSV53564949; called by mutect2, varscan2
- GFI1 | c.83G>A p.R28H | Missense Mutation (SNP) | VAF 70/318 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.355); catalogued as rs372866021; ClinVar: likely benign; called by muse, mutect2, varscan2
- GJA3 | c.771dup p.S258Qfs*68 | Frame Shift Ins (INS) | VAF 46/274 reads (17%) | catalogued as rs752926638; called by mutect2, pindel
- GLB1L2 | c.373G>A p.A125T | Missense Mutation (SNP) | VAF 42/310 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.273); catalogued as rs141480972; called by muse, mutect2, varscan2
- GLRB | c.435dup p.A146Cfs*3 | Frame Shift Ins (INS) | VAF 39/255 reads (15%) | catalogued as rs1253776114; called by mutect2, pindel, varscan2
- GORAB | c.522-3T>C | Splice Region (SNP) | VAF 45/267 reads (17%) | catalogued as rs1171025327; called by muse, mutect2, varscan2
- GPAT2 | c.1930C>T p.R644* | Nonsense Mutation (SNP) | VAF 19/270 reads (7%) | catalogued as rs766062836, COSV64003711; called by muse, mutect2
- GPC6 | c.421G>A p.D141N | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.33); catalogued as COSV104424980; called by muse, mutect2
- GPR158 | c.646G>A p.A216T | Missense Mutation (SNP) | VAF 37/168 reads (22%) | SIFT tolerated (0.58); PolyPhen benign (0.189); catalogued as rs968674168; called by muse, mutect2, varscan2
- GPR162 | c.662G>T p.G221V | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs782535794, COSV50589254; called by muse, mutect2
- GRAP | c.421G>A p.A141T | Missense Mutation (SNP) | VAF 30/184 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.505); catalogued as rs770213883; called by muse, varscan2
- GREM2 | c.382G>A p.V128I | Missense Mutation (SNP) | VAF 16/212 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as COSV100547720; called by muse, mutect2
- GRM1 | c.2734C>T p.R912C | Missense Mutation (SNP) | VAF 105/637 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as COSV51171747, COSV51300307; called by muse, mutect2, varscan2
- GTF3C1 | c.272C>T p.P91L | Missense Mutation (SNP) | VAF 50/264 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.163); catalogued as rs766261512, COSV55189032; called by muse, mutect2, varscan2
- HCFC1 | c.3517G>A p.A1173T | Missense Mutation (SNP) | VAF 21/149 reads (14%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); catalogued as rs782545202, COSV60074053; called by muse, mutect2, varscan2
- HCN4 | c.26G>A p.R9H | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs1045593470; called by muse, mutect2, varscan2
- HDAC1 | c.145C>T p.R49* | Nonsense Mutation (SNP) | VAF 31/135 reads (23%) | catalogued as rs1013856569, COSV101000398; called by muse, mutect2, varscan2
- HERPUD2 | c.764A>T p.E255V | Missense Mutation (SNP) | VAF 50/346 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.105); catalogued as COSV60947899; called by muse, mutect2, varscan2
- HMGCLL1 | c.988C>T p.L330F | Missense Mutation (SNP) | VAF 22/155 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs746837826; called by muse, mutect2, varscan2
- HPS3 | c.1190G>A p.R397Q | Missense Mutation (SNP) | VAF 41/309 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); catalogued as rs747708121, COSV56055621; called by muse, mutect2, varscan2
- HR | c.1052del p.G351Vfs*12 | Frame Shift Del (DEL) | VAF 28/186 reads (15%) | catalogued as rs750438737; called by mutect2, varscan2
- HSD17B1 | c.457A>G p.N153D | Missense Mutation (SNP) | VAF 42/184 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.229); catalogued as rs755663520; called by muse, mutect2, varscan2
- HSPA2 | c.395C>T p.A132V | Missense Mutation (SNP) | VAF 30/176 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.927); catalogued as rs775502313, COSV55971108; called by muse, varscan2
- HSPG2 | c.8018G>A p.R2673Q | Missense Mutation (SNP) | VAF 95/477 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.023); catalogued as rs778613352; called by muse, mutect2, varscan2
- HTR1E | c.623C>T p.A208V | Missense Mutation (SNP) | VAF 31/234 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1263006902, COSV59506673; called by muse, mutect2, varscan2
- HYAL1 | c.449G>A p.R150H | Missense Mutation (SNP) | VAF 54/677 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.042); catalogued as rs782788446, COSV56498883; called by muse, mutect2
- ICA1 | c.611del p.N204Tfs*5 | Frame Shift Del (DEL) | VAF 23/100 reads (23%) | catalogued as rs747841314; called by mutect2, varscan2
- IDUA | c.1781C>T p.P594L | Missense Mutation (SNP) | VAF 73/461 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs143621769, COSV56106439; called by muse, mutect2, varscan2
- IGFALS | c.1519C>T p.R507W | Missense Mutation (SNP) | VAF 132/746 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as rs1453837251; called by muse, mutect2, varscan2
- IGHMBP2 | c.1913C>T p.T638M | Missense Mutation (SNP) | VAF 30/438 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs747465472, COSV99661657; ClinVar: uncertain significance; called by muse, mutect2
- IGSF9 | c.2509C>T p.R837W (on ENST00000368094 / NM_001135050.2; = p.R821W on NM_020789.4) | Missense Mutation (SNP) | VAF 18/135 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.424); catalogued as rs774555800; called by muse, mutect2, varscan2
- IL1B | c.537G>T p.K179N | Missense Mutation (SNP) | VAF 112/709 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs774783730, COSV54522023; called by mutect2, varscan2
- IL27RA | c.1192G>A p.A398T | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.138); catalogued as rs1220906608; called by muse, mutect2
- INPP5D | c.2579C>T p.T860M (on ENST00000445964 / NM_001017915.3; = p.T859M on NM_005541.5) | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs556107769, COSV64036913; called by muse, mutect2, varscan2
- INPP5F | c.631del p.W211Gfs*5 | Frame Shift Del (DEL) | VAF 18/153 reads (12%) | catalogued as rs768918635; called by mutect2, pindel, varscan2
- IQGAP3 | c.2404C>T p.R802W | Missense Mutation (SNP) | VAF 48/250 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771371414, COSV63250417; called by muse, mutect2, varscan2
- ITGA2 | c.584dup p.L195Ffs*25 | Frame Shift Ins (INS) | VAF 43/294 reads (15%) | catalogued as rs1243641566; called by mutect2, pindel, varscan2
- ITGB4 | c.209C>T p.A70V | Missense Mutation (SNP) | VAF 77/580 reads (13%) | SIFT tolerated (0.57); PolyPhen benign (0.081); catalogued as rs747831589, COSV52325433; called by muse, mutect2, varscan2
- ITIH3 | c.2144T>C p.I715T | Missense Mutation (SNP) | VAF 87/478 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1170211295; called by muse, mutect2, varscan2
- JAKMIP3 | c.1309C>T p.R437W | Missense Mutation (SNP) | VAF 35/294 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs372342663, COSV53819499; called by muse, mutect2, varscan2
- JDP2 | c.334G>A p.A112T | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.04); catalogued as rs535492554; called by muse, mutect2, varscan2
- JHY | c.152C>T p.T51M | Missense Mutation (SNP) | VAF 38/213 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.42); catalogued as rs374078669; called by muse, mutect2, varscan2
- KBTBD13 | c.284G>A p.R95H | Missense Mutation (SNP) | VAF 31/162 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as rs1160768354; called by muse, mutect2, varscan2
- KBTBD6 | c.2009G>A p.R670H | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs1468053819, COSV65271200; called by muse, mutect2, varscan2
- KCNN1 | c.1192G>A p.V398I | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.889); catalogued as rs769914874, COSV55841698; called by muse, mutect2, varscan2
- KCNS1 | c.956C>T p.T319M | Missense Mutation (SNP) | VAF 64/316 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368885097; called by muse, mutect2, varscan2
- KCNT1 | c.827C>T p.A276V (on ENST00000488444; = p.A295V on NM_020822.3) | Missense Mutation (SNP) | VAF 17/158 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.147); catalogued as rs1272987725; called by muse, mutect2, varscan2
- KCNU1 | c.851C>T p.A284V | Missense Mutation (SNP) | VAF 31/189 reads (16%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.506); catalogued as COSV67753081; called by muse, mutect2, varscan2
- KCTD12 | c.551G>A p.R184H | Missense Mutation (SNP) | VAF 24/157 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.151); catalogued as COSV100499688; called by muse, mutect2, varscan2
- KIAA0100 | c.4070G>A p.R1357Q | Missense Mutation (SNP) | VAF 29/195 reads (15%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.988); catalogued as rs377173655; called by muse, mutect2, varscan2
- KLHL14 | c.275C>T p.P92L | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs1411272046; called by muse, mutect2, varscan2
- KLHL18 | c.1174G>A p.D392N | Missense Mutation (SNP) | VAF 21/153 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.811); catalogued as rs906891659; called by muse, mutect2, varscan2
- KRT74 | c.671A>G p.E224G | Missense Mutation (SNP) | VAF 70/471 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200232782; called by muse, mutect2, varscan2
- KRT79 | c.667G>A p.V223M | Missense Mutation (SNP) | VAF 48/454 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs201940037; called by muse, mutect2, varscan2
- KRTAP10-6 | c.312del p.C105Afs*75 | Frame Shift Del (DEL) | VAF 70/477 reads (15%) | catalogued as rs1555926830, COSV100551405; called by mutect2, pindel, varscan2
- LAIR1 | c.175C>T p.R59C | Missense Mutation (SNP) | VAF 22/422 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs745987558; called by muse, mutect2
- LAMA1 | c.3659G>A p.R1220Q | Missense Mutation (SNP) | VAF 37/263 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.459); catalogued as rs367987988; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LAMA5 | c.8530G>A p.V2844I | Missense Mutation (SNP) | VAF 14/147 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.04); catalogued as rs760179827, COSV53360082; called by muse, mutect2
- LAMA5 | c.3791G>A p.R1264Q | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs756189022, COSV53361493; called by muse, mutect2
- LARP4B | c.1348C>T p.R450W | Missense Mutation (SNP) | VAF 95/508 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60221713; called by muse, mutect2, varscan2
- LBH | c.275A>G p.Q92R | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.085); catalogued as rs1446609662; called by muse, mutect2, varscan2
- LDHD | c.677C>T p.P226L | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT tolerated, low confidence (0.92); PolyPhen benign (0.039); catalogued as COSV55580192; called by muse, mutect2, varscan2
- LGALS8 | c.284C>T p.T95M | Missense Mutation (SNP) | VAF 32/285 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs375572280; called by muse, mutect2, varscan2
- LRP1 | c.7208G>A p.R2403Q | Missense Mutation (SNP) | VAF 24/503 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs1357101794; called by muse, mutect2
- LRP1 | c.10234G>A p.V3412I | Missense Mutation (SNP) | VAF 30/169 reads (18%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.989); catalogued as rs150254492; called by muse, mutect2, varscan2
- LRRC56 | c.37C>T p.R13W | Missense Mutation (SNP) | VAF 34/188 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.034); catalogued as rs746762994; called by muse, mutect2, varscan2
- LRRC8C | c.1039C>T p.R347W | Missense Mutation (SNP) | VAF 56/402 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.184); catalogued as rs778820765, COSV64996845; called by muse, mutect2, varscan2
- LRRFIP1 | c.218G>A p.R73H | Missense Mutation (SNP) | VAF 13/148 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs764869813; called by mutect2, varscan2
- LRRN4 | c.1637C>T p.P546L | Missense Mutation (SNP) | VAF 21/119 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs987179908; called by muse, mutect2, varscan2
- LTB4R2 | c.1075C>T p.R359* (on ENST00000528054; = p.R328* on NM_019839.5) | Nonsense Mutation (SNP) | VAF 27/155 reads (17%) | catalogued as rs752448394; called by muse, mutect2, varscan2
- LTBP4 | c.2965C>T p.R989W (on ENST00000308370 / NM_001042544.1; = p.R952W on NM_003573.2) | Missense Mutation (SNP) | VAF 25/175 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs1441031158, COSV52584727; called by muse, mutect2, varscan2
- LTK | c.394G>A p.A132T | Missense Mutation (SNP) | VAF 43/150 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.952); catalogued as rs763872314; called by muse, mutect2, varscan2
- LY75 | c.4952A>G p.E1651G | Missense Mutation (SNP) | VAF 22/142 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.026); catalogued as rs115348342; called by muse, mutect2, varscan2
- MARS1 | c.212del p.L71Cfs*33 | Frame Shift Del (DEL) | VAF 24/132 reads (18%) | catalogued as rs751080704; called by mutect2, varscan2
- MBD6 | c.2345del p.G782Efs*13 | Frame Shift Del (DEL) | VAF 15/54 reads (28%) | catalogued as rs746267361; called by mutect2, varscan2
- MCM3AP | c.2074C>T p.R692W | Missense Mutation (SNP) | VAF 46/349 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99387205; called by muse, mutect2, varscan2
- MCM7 | c.2059C>T p.R687C | Missense Mutation (SNP) | VAF 66/333 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as rs146568179; called by muse, mutect2, varscan2
- MED25 | c.602del p.P201Rfs*13 | Frame Shift Del (DEL) | VAF 50/290 reads (17%) | catalogued as rs748546983; ClinVar: uncertain significance; called by mutect2, varscan2
- MEDAG | c.206del p.G69Afs*29 | Frame Shift Del (DEL) | VAF 15/123 reads (12%) | catalogued as rs745558596; called by mutect2, pindel, varscan2
- MEI1 | c.1075del p.S359Pfs*13 | Frame Shift Del (DEL) | VAF 28/149 reads (19%) | catalogued as rs1280411643; called by mutect2, varscan2
- MEN1 | c.670-5del | Splice Region (DEL) | VAF 37/303 reads (12%) | catalogued as rs772016629; ClinVar: benign / likely benign; called by mutect2, pindel, varscan2
- MMEL1 | c.84dup p.L29Afs*32 | Frame Shift Ins (INS) | VAF 18/156 reads (12%) | catalogued as rs1168749408; called by mutect2, varscan2
- MMP11 | c.275G>A p.R92H | Missense Mutation (SNP) | VAF 61/426 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.019); catalogued as rs139978312; called by muse, mutect2, varscan2
- MMP15 | c.262C>T p.R88C | Missense Mutation (SNP) | VAF 33/192 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); catalogued as rs1270428096; called by muse, mutect2, varscan2
- MMRN2 | c.796G>A p.V266M | Missense Mutation (SNP) | VAF 59/335 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.615); catalogued as rs200581114; called by muse, mutect2, varscan2
- MN1 | c.1394C>T p.A465V | Missense Mutation (SNP) | VAF 36/191 reads (19%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.038); catalogued as COSV56559505; called by muse, varscan2
- MOGS | c.758C>T p.T253I | Missense Mutation (SNP) | VAF 35/258 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.112); catalogued as COSV99280996; called by muse, mutect2, varscan2
- MRGPRG | c.379G>A p.A127T | Missense Mutation (SNP) | VAF 22/127 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.134); catalogued as rs770016582; called by muse, mutect2, varscan2
- MROH5 | c.3449C>T p.A1150V | Missense Mutation (SNP) | VAF 20/189 reads (11%) | SIFT tolerated (0.42); PolyPhen benign (0.157); catalogued as rs753528694, COSV61471091; called by muse, mutect2, varscan2
- MROH9 | c.2353C>T p.R785* | Nonsense Mutation (SNP) | VAF 18/107 reads (17%) | catalogued as rs748211477; called by muse, mutect2, varscan2
- MSC | c.139G>A p.A47T | Missense Mutation (SNP) | VAF 24/133 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs1488711959, COSV57696612; called by muse, mutect2, varscan2
- MTNR1B | c.461G>A p.R154H | Missense Mutation (SNP) | VAF 59/454 reads (13%) | SIFT tolerated (0.59); PolyPhen benign (0.009); catalogued as rs751169692; called by muse, mutect2, varscan2
- MTOR | c.5452C>T p.R1818C | Missense Mutation (SNP) | VAF 40/260 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs759603938, COSV63867983; called by muse, mutect2, varscan2
- MTOR | c.4918C>T p.R1640W | Missense Mutation (SNP) | VAF 30/199 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs766533620, COSV63868467; called by muse, mutect2, varscan2
- MUC16 | c.11563C>A p.Q3855K | Missense Mutation (SNP) | VAF 34/227 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.038); catalogued as rs1042024592; called by mutect2, varscan2
- MVD | c.344T>C p.V115A | Missense Mutation (SNP) | VAF 35/252 reads (14%) | SIFT tolerated (0.5); PolyPhen benign (0.036); catalogued as COSV99964847; called by muse, mutect2, varscan2
- MYLK | c.2729T>C p.L910P | Missense Mutation (SNP) | VAF 32/810 reads (4%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.629); catalogued as rs1392489184; called by muse, mutect2
- MYO1F | c.1621C>T p.R541W | Missense Mutation (SNP) | VAF 26/167 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as rs371759403; called by muse, mutect2, varscan2
- MYOM3 | c.121C>T p.R41C | Missense Mutation (SNP) | VAF 27/174 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.109); catalogued as rs976472393; called by muse, mutect2, varscan2
- N4BP1 | c.1874G>A p.S625N | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as COSV99285137; called by muse, mutect2, varscan2
- NAGK | c.766-5C>T | Splice Region (SNP) | VAF 10/84 reads (12%) | catalogued as rs765396638; called by mutect2, varscan2
- NBPF9 | c.44T>C p.M15T | Missense Mutation (SNP) | VAF 46/344 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.781); catalogued as rs1375944245; called by muse, mutect2, varscan2
- NEFM | c.1433A>G p.E478G | Missense Mutation (SNP) | VAF 22/156 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.084); catalogued as rs768247534; called by muse, mutect2, varscan2
- NEIL1 | c.383del p.K128Sfs*25 | Frame Shift Del (DEL) | VAF 29/186 reads (16%) | catalogued as rs764077762; called by mutect2, pindel, varscan2
- NKX2-8 | c.260G>A p.R87Q | Missense Mutation (SNP) | VAF 35/175 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV51874326; called by muse, mutect2, varscan2
- NKX3-2 | c.142G>A p.A48T | Missense Mutation (SNP) | VAF 33/160 reads (21%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.028); catalogued as rs1215209223, COSV66711676; called by muse, mutect2, varscan2
- NLRC5 | c.1346del p.P449Lfs*17 | Frame Shift Del (DEL) | VAF 46/288 reads (16%) | catalogued as rs772651939; called by mutect2, pindel, varscan2
- NLRP8 | c.1799C>A p.P600H | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.763); catalogued as COSV99405415; called by mutect2, varscan2
- NOTCH4 | c.5039G>A p.R1680Q | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs766378003; called by muse, mutect2
- NOX3 | c.752C>T p.T251I | Missense Mutation (SNP) | VAF 28/184 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as COSV50154858; called by muse, mutect2, varscan2
- NOX5 | c.652del p.R218Afs*10 | Frame Shift Del (DEL) | VAF 6/27 reads (22%) | catalogued as rs777268755; called by mutect2, pindel, varscan2
- NUP214 | c.369del p.F123Lfs*23 | Frame Shift Del (DEL) | VAF 15/89 reads (17%) | catalogued as rs1339521249; called by mutect2, pindel, varscan2
- NUTM1 | c.1525C>T p.R509W | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as rs777144164, COSV59215633; called by muse, mutect2, varscan2
- NUTM2G | c.212G>A p.R71H | Missense Mutation (SNP) | VAF 49/392 reads (13%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as rs750368076; called by muse, mutect2, varscan2
- NYAP2 | c.703G>A p.A235T | Missense Mutation (SNP) | VAF 31/230 reads (13%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as rs551352616, COSV55999744; called by muse, mutect2, varscan2
- OBSCN | c.3317C>T p.T1106M | Missense Mutation (SNP) | VAF 69/369 reads (19%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.909); catalogued as rs368159429; called by muse, mutect2, varscan2
- OBSCN | c.19048G>A p.D6350N | Missense Mutation (SNP) | VAF 31/197 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs374006342; called by muse, mutect2, varscan2
- OBSL1 | c.4294C>T p.R1432W | Missense Mutation (SNP) | VAF 38/205 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs774564230; called by muse, mutect2, varscan2
- OPTC | c.685C>T p.R229C | Missense Mutation (SNP) | VAF 45/432 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs150633473, COSV65867446; called by muse, mutect2, varscan2
- OR10Z1 | c.355G>A p.G119S | Missense Mutation (SNP) | VAF 47/276 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.074); catalogued as COSV63526176, COSV63526375; called by muse, mutect2, varscan2
- OR11H1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 40/415 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.029); catalogued as rs1487599161, COSV99421536; called by muse, mutect2, varscan2
- OR2AG2 | c.475C>T p.H159Y | Missense Mutation (SNP) | VAF 14/386 reads (4%) | SIFT tolerated (0.9); PolyPhen benign (0.006); catalogued as rs1467458150, COSV99080748; called by muse, mutect2
- OR2B2 | c.742G>A p.V248M | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57579157; called by muse, mutect2, varscan2
- OR2Y1 | c.829del p.Y277Ifs*3 | Frame Shift Del (DEL) | VAF 33/186 reads (18%) | catalogued as COSV57137289; called by mutect2, pindel, varscan2
- OR4D6 | c.405G>A p.M135I | Missense Mutation (SNP) | VAF 21/173 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55658945; called by muse, mutect2, varscan2
- OR4K17 | c.363C>A p.D121E | Missense Mutation (SNP) | VAF 33/262 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59647880; called by muse, mutect2, varscan2
- OR4S1 | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 47/320 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.033); catalogued as rs545552726; called by muse, mutect2, varscan2
- OR52E8 | c.491C>A p.P164Q | Missense Mutation (SNP) | VAF 59/370 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101190649; called by muse, mutect2, varscan2
- OR5AK2 | c.290G>A p.C97Y | Missense Mutation (SNP) | VAF 40/414 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100476187; called by muse, mutect2
- OR5AR1 | c.924del p.K308Nfs*8 | Frame Shift Del (DEL) | VAF 10/92 reads (11%) | catalogued as rs1179572364; called by mutect2, pindel, varscan2
- OR6C3 | c.446G>A p.G149E | Missense Mutation (SNP) | VAF 35/234 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.864); catalogued as rs1240887929; called by muse, mutect2, varscan2
- OR8H3 | c.616del p.T206Pfs*2 | Frame Shift Del (DEL) | VAF 31/255 reads (12%) | catalogued as COSV57911943; called by mutect2, varscan2
- OR8U1 | c.716C>T p.S239L | Missense Mutation (SNP) | VAF 39/264 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.415); catalogued as rs764656297, COSV56414529; called by muse, varscan2
- OSBPL3 | c.686G>A p.C229Y | Missense Mutation (SNP) | VAF 20/136 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1399761460; called by muse, mutect2
- OTOF | c.4921C>T p.R1641C (on ENST00000272371 / NM_194248.3; = p.R874C on NM_004802.4) | Missense Mutation (SNP) | VAF 50/193 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as rs1264877874, COSV55507037; called by muse, mutect2, varscan2
- OTUD7A | c.326C>T p.A109V | Missense Mutation (SNP) | VAF 18/136 reads (13%) | SIFT tolerated (1); PolyPhen possibly damaging (0.453); catalogued as COSV61041741; called by muse, mutect2, varscan2
- OVOL2 | c.502A>G p.T168A | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53859914; called by muse, mutect2
- P2RY8 | c.718G>A p.A240T | Missense Mutation (SNP) | VAF 53/258 reads (21%) | SIFT tolerated (0.56); PolyPhen benign (0.023); catalogued as rs754515395; called by muse, mutect2, varscan2
- PADI2 | c.1712C>T p.A571V | Missense Mutation (SNP) | VAF 38/203 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.07); catalogued as COSV100972022; called by muse, mutect2, varscan2
- PAX1 | c.163G>A p.A55T | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.084); catalogued as rs980987969; called by muse, varscan2
- PBRM1 | c.604C>T p.R202C | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs765525545, COSV56298928; called by mutect2, varscan2
- PCDH11X | c.2510G>A p.R837H | Missense Mutation (SNP) | VAF 53/390 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.075); catalogued as rs768277417, COSV53461734; called by muse, mutect2, varscan2
- PCDH11X | c.3701G>A p.S1234N | Missense Mutation (SNP) | VAF 44/652 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); catalogued as rs373650412, COSV100013400, COSV53479414; called by muse, mutect2
- PCDH12 | c.400C>T p.R134W | Missense Mutation (SNP) | VAF 24/159 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.328); catalogued as rs751221718, COSV51524729; called by muse, mutect2, varscan2
- PCDH17 | c.634G>A p.V212M | Missense Mutation (SNP) | VAF 64/568 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.686); catalogued as COSV64979996; called by muse, mutect2, varscan2
- PCDH9 | c.346G>T p.V116L | Missense Mutation (SNP) | VAF 21/176 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.626); catalogued as COSV100118543; called by muse, mutect2, varscan2
- PCDHA3 | c.596del p.N199Ifs*2 | Frame Shift Del (DEL) | VAF 28/137 reads (20%) | catalogued as rs782411180, COSV65371489; called by mutect2, varscan2
- PCDHB1 | c.83C>T p.A28V | Missense Mutation (SNP) | VAF 35/214 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV60631214; called by muse, mutect2, varscan2
- PCDHB2 | c.2039C>T p.P680L | Missense Mutation (SNP) | VAF 106/604 reads (18%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); catalogued as COSV50613920; called by muse, mutect2, varscan2
- PCDHB7 | c.28C>T p.Q10* | Nonsense Mutation (SNP) | VAF 26/130 reads (20%) | catalogued as COSV50757983; called by muse, mutect2, varscan2
- PCDHGA3 | c.1636G>A p.V546M | Missense Mutation (SNP) | VAF 133/724 reads (18%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.378); catalogued as COSV53938956; called by muse, mutect2, varscan2
- PCDHGA6 | c.1552C>T p.R518C | Missense Mutation (SNP) | VAF 79/429 reads (18%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.024); catalogued as rs776372663, COSV54013037; called by muse, mutect2, varscan2
- PCDHGB2 | c.892dup p.T298Nfs*9 | Frame Shift Ins (INS) | VAF 27/172 reads (16%) | catalogued as rs758957504; called by mutect2, pindel, varscan2
- PCSK4 | c.592C>T p.R198W | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.167); catalogued as rs774830559, COSV52013109; called by mutect2, varscan2
- PDCD10 | c.584A>G p.N195S | Missense Mutation (SNP) | VAF 22/257 reads (9%) | SIFT tolerated (0.73); PolyPhen benign (0.146); catalogued as rs1421783974; called by muse, mutect2
- PDP1 | c.1115G>A p.G372D | Missense Mutation (SNP) | VAF 91/743 reads (12%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.978); catalogued as COSV52603432; called by muse, mutect2, varscan2
- PGAP4 | c.295del p.R99Gfs*5 | Frame Shift Del (DEL) | VAF 28/174 reads (16%) | catalogued as rs765092936; called by mutect2, pindel, varscan2
- PHACTR4 | c.160del p.S54Vfs*12 (on ENST00000373839 / NM_001350159.2; = p.S64Vfs*12 on NM_023923.4) | Frame Shift Del (DEL) | VAF 20/74 reads (27%) | catalogued as rs761437290, COSV65783432; called by mutect2, varscan2
- PHACTR4 | c.1972C>T p.R658W (on ENST00000373839 / NM_001350159.2; = p.R668W on NM_023923.4) | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758350018, COSV100868451; called by mutect2, varscan2
- PHETA1 | c.326C>T p.S109L | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs144801881; called by muse, mutect2, varscan2
- PHF13 | c.857G>A p.R286H | Missense Mutation (SNP) | VAF 28/406 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1447724868, COSV99275449; called by muse, mutect2
- PHF20 | c.2642del p.P881Rfs*7 | Frame Shift Del (DEL) | VAF 18/105 reads (17%) | catalogued as COSV64976471; called by mutect2, pindel, varscan2
- PIAS3 | c.1766del p.P589Lfs*15 | Frame Shift Del (DEL) | VAF 19/99 reads (19%) | catalogued as COSV57906572; called by mutect2, pindel, varscan2
- PICK1 | c.478G>A p.A160T | Missense Mutation (SNP) | VAF 35/229 reads (15%) | SIFT tolerated (0.41); PolyPhen benign (0.097); catalogued as rs1460371188; called by muse, mutect2, varscan2
- PIK3C3 | c.2112del p.F704Lfs*31 | Frame Shift Del (DEL) | VAF 26/106 reads (25%) | catalogued as COSV56275924; called by mutect2, pindel, varscan2
- PITPNM1 | c.593G>A p.R198H | Missense Mutation (SNP) | VAF 36/297 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs1201409699; called by muse, mutect2, varscan2
- PITPNM2 | c.3463G>A p.D1155N | Missense Mutation (SNP) | VAF 27/191 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs747118433; called by muse, mutect2, varscan2
- PIWIL4 | c.68G>A p.R23H | Missense Mutation (SNP) | VAF 36/206 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs772344895, COSV54408547; called by muse, mutect2, varscan2
- PKD1 | c.2854-5del | Splice Region (DEL) | VAF 30/217 reads (14%) | catalogued as rs755005894; called by mutect2, pindel, varscan2
- PKD1L2 | n.430del | Splice Region (DEL) | VAF 8/76 reads (11%) | catalogued as rs755082958; called by mutect2, varscan2
- PKD1L2 | c.331G>A p.V111M | Missense Mutation (SNP) | VAF 29/132 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as rs1354866598; called by muse, mutect2, varscan2
- PKHD1 | c.10693C>A p.L3565I | Missense Mutation (SNP) | VAF 88/563 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs1426139137; called by mutect2, varscan2
- PLAUR | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs1378221413, COSV55388633; called by muse, mutect2, varscan2
- PLCD4 | c.961G>A p.E321K | Missense Mutation (SNP) | VAF 39/214 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771868964; called by muse, mutect2, varscan2
- PLEKHG4 | c.1720C>T p.R574* | Nonsense Mutation (SNP) | VAF 36/258 reads (14%) | catalogued as rs551905408; called by muse, mutect2, varscan2
- PLPBP | c.695C>T p.A232V | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs777815255; called by muse, mutect2, varscan2
- PLPPR5 | c.651G>T p.K217N | Missense Mutation (SNP) | VAF 19/157 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.37); catalogued as COSV99587674; called by muse, mutect2, varscan2
- PLPPR5 | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 82/459 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs771583208, COSV54176975; called by muse, mutect2, varscan2
- PLXNA1 | c.2824C>T p.R942W | Missense Mutation (SNP) | VAF 33/273 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs925924527; called by muse, mutect2, varscan2
- PLXNA3 | c.49del p.A17Pfs*12 | Frame Shift Del (DEL) | VAF 32/307 reads (10%) | catalogued as rs782247826; called by mutect2, varscan2
- PLXNA4 | c.5264C>T p.P1755L | Missense Mutation (SNP) | VAF 30/155 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759002592; called by muse, mutect2, varscan2
- PLXNC1 | c.288del p.A97Rfs*46 | Frame Shift Del (DEL) | VAF 7/91 reads (8%) | catalogued as rs1555192596; called by mutect2, pindel
- POLE | c.4493C>T p.A1498V | Missense Mutation (SNP) | VAF 29/306 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.093); catalogued as rs751465593; ClinVar: uncertain significance; called by muse, mutect2
- POR | c.1103C>T p.T368M | Missense Mutation (SNP) | VAF 22/246 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.656); catalogued as rs377500167; called by muse, mutect2
- POTEC | c.466G>C p.D156H | Missense Mutation (SNP) | VAF 51/362 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV62800685, COSV62802929; called by mutect2, varscan2
- POU4F3 | c.232G>A p.A78T | Missense Mutation (SNP) | VAF 95/674 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as rs148830499; called by muse, mutect2, varscan2
- PPIP5K1 | c.928G>A p.V310I | Missense Mutation (SNP) | VAF 52/604 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs375346178; called by muse, mutect2
- PPL | c.5210G>A p.R1737H | Missense Mutation (SNP) | VAF 35/208 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.212); catalogued as rs138719513; called by muse, mutect2, varscan2
- PPM1J | c.850_852del p.I284del | In Frame Del (DEL) | VAF 15/131 reads (11%) | catalogued as rs1557783463; called by mutect2, pindel, varscan2
- PPP2R3B | c.1165dup p.T389Nfs*62 | Frame Shift Ins (INS) | VAF 28/150 reads (19%) | catalogued as rs1343970419; called by mutect2, varscan2
- PPP4R3C | c.776T>G p.L259R | Missense Mutation (SNP) | VAF 28/358 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101297303; called by muse, mutect2
- PRDM2 | c.1214G>A p.R405Q | Missense Mutation (SNP) | VAF 31/168 reads (18%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as rs149263598; called by muse, mutect2, varscan2
- PRPH | c.1376G>A p.R459H | Missense Mutation (SNP) | VAF 40/285 reads (14%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs982729267; called by muse, mutect2, varscan2
- PRSS55 | c.808A>G p.I270V | Missense Mutation (SNP) | VAF 19/153 reads (12%) | SIFT tolerated (0.42); PolyPhen benign (0.228); catalogued as COSV100153841; called by muse, mutect2, varscan2
- PTAR1 | c.524G>A p.R175Q | Missense Mutation (SNP) | VAF 66/355 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs778437482; called by muse, varscan2
- PTPRD | c.2398G>A p.V800I | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.721); catalogued as rs201412075, COSV61960470; called by mutect2, varscan2
- PTPRD | c.751G>A p.G251R | Missense Mutation (SNP) | VAF 47/278 reads (17%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.758); catalogued as rs758577045, COSV100642816, COSV61995148; called by muse, mutect2, varscan2
- PTPRS | c.3581G>A p.R1194H | Missense Mutation (SNP) | VAF 30/184 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.886); catalogued as rs115469963; called by muse, mutect2, varscan2
- PYROXD2 | c.1193C>T p.P398L | Missense Mutation (SNP) | VAF 27/135 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs763571324; called by muse, mutect2, varscan2
- RAB11FIP3 | c.2002C>T p.R668C | Missense Mutation (SNP) | VAF 32/187 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV51930478; called by muse, mutect2, varscan2
- RABGGTA | c.115C>T p.R39C | Missense Mutation (SNP) | VAF 25/156 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs767225082; called by muse, mutect2, varscan2
- RAC1 | c.515C>T p.A172V | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.446); catalogued as COSV100641113; called by muse, mutect2, varscan2
- RALGAPA2 | c.433G>A p.A145T | Missense Mutation (SNP) | VAF 29/182 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs1336269888; called by muse, mutect2, varscan2
- RASA1 | c.2641G>C p.V881L | Missense Mutation (SNP) | VAF 43/296 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99170286; called by muse, mutect2, varscan2
- RASAL2 | c.3051G>T p.Q1017H | Missense Mutation (SNP) | VAF 27/115 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs866261915; called by muse, mutect2, varscan2
- RBM15B | c.1541C>T p.T514I | Missense Mutation (SNP) | VAF 44/289 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as COSV60041575, COSV60045165; called by muse, mutect2, varscan2
- RBM28 | c.2074G>A p.V692I | Missense Mutation (SNP) | VAF 67/429 reads (16%) | SIFT tolerated (0.43); PolyPhen benign (0.006); catalogued as rs150722434; called by muse, mutect2, varscan2
- REEP4 | c.704G>A p.R235Q | Missense Mutation (SNP) | VAF 42/248 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.143); catalogued as rs748543991; called by muse, mutect2, varscan2
- REPIN1 | c.1116del p.S373Pfs*242 | Frame Shift Del (DEL) | VAF 10/66 reads (15%) | catalogued as rs759247453; called by mutect2, varscan2
- RESF1 | c.1093G>T p.A365S | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.045); catalogued as COSV57023064; called by muse, mutect2, varscan2
- RGL2 | c.1012G>A p.V338M | Missense Mutation (SNP) | VAF 27/176 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV65842065, COSV65842262; called by muse, mutect2, varscan2
- RGMA | c.748G>A p.G250S | Missense Mutation (SNP) | VAF 52/394 reads (13%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as rs1239567004, COSV61233859; called by muse, mutect2, varscan2
- RHAG | c.205A>G p.M69V | Missense Mutation (SNP) | VAF 77/517 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs752360703; called by muse, mutect2, varscan2
- RHPN1 | c.722G>A p.R241H | Missense Mutation (SNP) | VAF 15/134 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.006); catalogued as rs768353758, COSV100000839; called by muse, mutect2, varscan2
- RND3 | c.391C>T p.L131F | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.965); catalogued as rs142625334; called by muse, mutect2, varscan2
- RNF128 | c.31del p.W11Gfs*4 | Frame Shift Del (DEL) | VAF 10/68 reads (15%) | catalogued as rs757038390; called by mutect2, varscan2
- RNF19A | c.125G>A p.R42Q | Missense Mutation (SNP) | VAF 46/327 reads (14%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.968); catalogued as rs201554011, COSV61993065; called by muse, mutect2, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 40/128 reads (31%) | catalogued as rs755128667, COSV68457540; called by mutect2, pindel, varscan2
- RNPC3 | c.473A>G p.K158R | Missense Mutation (SNP) | VAF 24/151 reads (16%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.996); catalogued as rs1279906504; called by muse, mutect2, varscan2
- ROR1 | c.1173C>T p.C391= | Splice Region (SNP) | VAF 43/196 reads (22%) | catalogued as rs763495095, COSV64286685, COSV64289643; called by muse, mutect2, varscan2
- RPS6KB2 | c.728G>A p.R243H | Missense Mutation (SNP) | VAF 45/285 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.461); catalogued as COSV100396239; called by muse, mutect2, varscan2
- RTN2 | c.178del p.R60Gfs*3 | Frame Shift Del (DEL) | VAF 33/219 reads (15%) | catalogued as COSV55595576; called by mutect2, pindel, varscan2
- RYR1 | c.2506C>A p.P836T | Missense Mutation (SNP) | VAF 72/437 reads (16%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.474); catalogued as COSV100615748; called by muse, mutect2, varscan2
- RYR2 | c.4739C>T p.P1580L | Missense Mutation (SNP) | VAF 24/165 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as rs755303612; called by muse, mutect2, varscan2
- SAG | c.1054G>A p.A352T | Missense Mutation (SNP) | VAF 40/266 reads (15%) | SIFT tolerated (0.49); PolyPhen benign (0.391); catalogued as rs201307508; ClinVar: uncertain significance; called by muse, varscan2
- SALL3 | c.3319C>T p.R1107C | Missense Mutation (SNP) | VAF 39/218 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs748645061, COSV73306077; called by muse, mutect2, varscan2
- SAT2 | c.13C>T p.R5W | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.332); catalogued as rs753348551, COSV52647873; called by mutect2, varscan2
- SCAPER | c.2613del p.A872Pfs*4 | Frame Shift Del (DEL) | VAF 12/50 reads (24%) | catalogued as rs757259031; called by mutect2, varscan2
- SCN10A | c.3224C>T p.A1075V | Missense Mutation (SNP) | VAF 27/198 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.061); catalogued as COSV71861582; called by muse, mutect2, varscan2
- SCN1A | c.1703G>A p.R568Q | Missense Mutation (SNP) | VAF 42/276 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs794727025, COSV57668384; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCYL3 | c.1060C>T p.R354W | Missense Mutation (SNP) | VAF 37/245 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63044388; called by muse, mutect2, varscan2
- SEBOX | c.325C>T p.P109S | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs782486242, COSV52648160; called by muse, mutect2, varscan2
- SEMA3B | c.196C>T p.R66C | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs370904521; called by muse, mutect2
- SEMA4C | c.1867G>A p.G623R | Missense Mutation (SNP) | VAF 46/268 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100560763; called by muse, mutect2, varscan2
- SEPTIN3 | c.175G>A p.G59S | Missense Mutation (SNP) | VAF 28/149 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.227); catalogued as rs1288451801; called by muse, mutect2, varscan2
- SEPTIN9 | c.980C>T p.S327L (on ENST00000427177 / NM_001113491.2; = p.S309L on NM_006640.4) | Missense Mutation (SNP) | VAF 38/321 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs763816708; called by muse, mutect2, varscan2
- SFPQ | c.1822A>G p.R608G | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); catalogued as COSV61758384; called by muse, mutect2
- SFTPA2 | c.136G>A p.G46R | Missense Mutation (SNP) | VAF 86/679 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772763289; called by muse, mutect2, varscan2
- SGO1 | c.973del p.M325Cfs*28 | Frame Shift Del (DEL) | VAF 26/150 reads (17%) | catalogued as rs747473028; called by mutect2, varscan2
- SH3BP4 | c.1861G>A p.G621R | Missense Mutation (SNP) | VAF 59/271 reads (22%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.781); catalogued as rs1215633310; called by muse, mutect2, varscan2
- SLC10A4 | c.221C>T p.A74V | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.018); catalogued as rs1248033073; called by muse, mutect2, varscan2
- SLC19A3 | c.172G>A p.V58I | Missense Mutation (SNP) | VAF 64/370 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.258); catalogued as rs200412423, COSV51453210; called by muse, mutect2, varscan2
- SLC1A1 | c.497G>A p.R166H | Missense Mutation (SNP) | VAF 41/237 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0.013); catalogued as rs775390587; called by muse, mutect2, varscan2
- SLC25A23 | c.242G>A p.R81H | Missense Mutation (SNP) | VAF 22/154 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.086); catalogued as rs140844848; called by muse, mutect2, varscan2
- SLC45A4 | c.1405C>T p.R469W (on ENST00000517878 / NM_001286646.2; = p.R418W on NM_001080431.2) | Missense Mutation (SNP) | VAF 48/436 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs746845858; called by muse, mutect2, varscan2
- SLC47A2 | c.1051C>T p.R351* | Nonsense Mutation (SNP) | VAF 8/43 reads (19%) | catalogued as rs369994046; called by mutect2, varscan2
- SLC6A19 | c.1063G>A p.V355M | Missense Mutation (SNP) | VAF 122/679 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.426); catalogued as rs1367901622; called by muse, mutect2, varscan2
- SLC9A5 | c.1636G>A p.V546I | Missense Mutation (SNP) | VAF 10/160 reads (6%) | SIFT tolerated (0.5); PolyPhen benign (0.005); catalogued as rs1335562611, COSV55362046; called by muse, mutect2
- SLFN11 | c.2020C>T p.R674C | Missense Mutation (SNP) | VAF 14/155 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.33); catalogued as rs201406101; called by muse, mutect2, varscan2
- SMAD4 | c.1393G>A p.V465M | Missense Mutation (SNP) | VAF 26/157 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); catalogued as rs786201798, CM1111086, COSV100748290; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SMC5 | c.3281G>A p.R1094H | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.894); catalogued as rs367938382; called by muse, mutect2, varscan2
- SMYD3 | c.878T>A p.I293N (on ENST00000490107 / NM_001375962.1; = p.I234N on NM_022743.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/152 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); catalogued as COSV63626122; called by mutect2, varscan2
- SNX25 | c.1913del p.N638Ifs*51 | Frame Shift Del (DEL) | VAF 26/138 reads (19%) | catalogued as rs768873484; called by mutect2, varscan2
- SORT1 | c.1174C>T p.R392* | Nonsense Mutation (SNP) | VAF 23/126 reads (18%) | catalogued as COSV56666397; called by muse, mutect2, varscan2
- SPART | c.649G>A p.D217N | Missense Mutation (SNP) | VAF 52/414 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as rs912926062, COSV100768742; called by muse, mutect2, varscan2
- SPATA31E1 | c.3212G>A p.G1071E | Missense Mutation (SNP) | VAF 49/399 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.918); catalogued as COSV57792463; called by muse, mutect2, varscan2
- SPEF1 | c.349C>T p.R117C | Missense Mutation (SNP) | VAF 40/179 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.869); catalogued as rs1278944165; called by muse, mutect2, varscan2
- SPEM2 | c.64G>A p.D22N | Missense Mutation (SNP) | VAF 22/141 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.012); catalogued as rs906192506, COSV60366626; called by muse, varscan2
- SPTB | c.1246C>T p.R416W | Missense Mutation (SNP) | VAF 102/565 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756541394; called by muse, mutect2, varscan2
- SPTBN5 | c.2405G>A p.R802Q | Missense Mutation (SNP) | VAF 31/182 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as rs761932649; called by muse, mutect2, varscan2
- SRF | c.1241C>T p.A414V | Missense Mutation (SNP) | VAF 34/197 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.138); catalogued as rs1336759405, COSV104373666; called by muse, mutect2, varscan2
- SRP72 | c.25del p.V9Cfs*10 | Frame Shift Del (DEL) | VAF 9/66 reads (14%) | catalogued as rs763130641; called by mutect2, pindel, varscan2
- SRRM4 | c.619C>T p.R207C | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.911); catalogued as rs368516977; called by muse, mutect2, varscan2
- STARD9 | c.475C>T p.R159W | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750197705; called by muse, mutect2, varscan2
- SUN2 | c.2122C>T p.R708C | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53283953; called by muse, mutect2, varscan2
- SUN3 | c.46C>T p.R16C | Missense Mutation (SNP) | VAF 19/135 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.043); catalogued as rs969807123; called by muse, mutect2, varscan2
- SUPT20HL2 | c.311G>A p.R104Q | Missense Mutation (SNP) | VAF 24/244 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.041); catalogued as rs749943332; called by muse, mutect2, varscan2
- SUV39H1 | c.776G>A p.R259H | Missense Mutation (SNP) | VAF 12/191 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV104401815; called by muse, mutect2
- SV2A | c.785G>A p.R262H | Missense Mutation (SNP) | VAF 17/125 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1439476158, COSV64964955; called by muse, mutect2, varscan2
- SYCP2L | c.818C>T p.T273M | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767257890, COSV51654714; called by muse, mutect2, varscan2
- SYMPK | c.3130C>T p.R1044C | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs776616150; called by muse, mutect2, varscan2
- SYNM | c.1375G>A p.V459I | Missense Mutation (SNP) | VAF 38/197 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.013); catalogued as rs782690979, COSV60367207; called by muse, mutect2, varscan2
- TAS1R3 | c.1812del p.L606Wfs*43 | Frame Shift Del (DEL) | VAF 40/240 reads (17%) | catalogued as rs777573279, COSV100229689; called by mutect2, pindel, varscan2
- TBC1D25 | c.1298C>T p.S433L | Missense Mutation (SNP) | VAF 44/292 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.259); catalogued as rs1556985728, COSV65123510; called by muse, mutect2, varscan2
- TBX15 | c.1337T>C p.L446P (on ENST00000369429 / NM_001330677.2; = p.L340P on NM_152380.3) | Missense Mutation (SNP) | VAF 139/806 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.931); catalogued as rs1344727300; called by muse, mutect2, varscan2
- TCP1 | c.1564A>G p.I522V | Missense Mutation (SNP) | VAF 52/330 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.1); catalogued as COSV58460241; called by muse, mutect2, varscan2
- TEKT2 | c.367C>T p.R123W | Missense Mutation (SNP) | VAF 69/414 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1340929223; called by muse, mutect2, varscan2
- TENM3 | c.1378C>T p.R460W | Missense Mutation (SNP) | VAF 49/282 reads (17%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.982); catalogued as rs773984641, COSV69306140; called by muse, mutect2, varscan2
- TENM4 | c.158G>A p.R53H | Missense Mutation (SNP) | VAF 91/523 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as CM1511326, COSV53679592; called by muse, mutect2, varscan2
- TESK1 | c.1874G>A p.R625H | Missense Mutation (SNP) | VAF 21/119 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.749); catalogued as rs753068416; called by muse, mutect2, varscan2
- TG | c.7133G>A p.R2378Q | Missense Mutation (SNP) | VAF 178/640 reads (28%) | SIFT tolerated (0.45); PolyPhen benign (0.027); catalogued as rs747373357, COSV55078611; called by muse, mutect2, varscan2
- THBS2 | c.1549C>T p.R517C | Missense Mutation (SNP) | VAF 29/174 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.162); catalogued as rs762558916; called by muse, mutect2, varscan2
- THSD7A | c.4559C>T p.P1520L | Missense Mutation (SNP) | VAF 23/160 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.02); catalogued as rs1189157566, COSV68472270; called by muse, mutect2, varscan2
- TLL1 | c.992G>A p.R331H | Missense Mutation (SNP) | VAF 62/510 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.687); catalogued as rs377432062, COSV50284047; called by muse, mutect2, varscan2
- TMEM247 | c.347C>T p.T116M | Missense Mutation (SNP) | VAF 28/318 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.882); catalogued as rs975902751; called by muse, mutect2
- TMEM94 | c.2682del p.S895Pfs*13 | Frame Shift Del (DEL) | VAF 29/136 reads (21%) | catalogued as rs747222326; called by mutect2, pindel, varscan2
- TNP2 | c.170G>A p.R57H | Missense Mutation (SNP) | VAF 34/205 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs373411423; called by muse, mutect2, varscan2
- TNRC18 | c.859G>A p.G287S | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.862); catalogued as rs1436985937; called by muse, mutect2, varscan2
- TOMM40 | c.652G>A p.V218I | Missense Mutation (SNP) | VAF 24/150 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.172); catalogued as rs781291864; called by muse, mutect2, varscan2
- TOP1MT | c.1378C>T p.R460* | Nonsense Mutation (SNP) | VAF 46/353 reads (13%) | catalogued as rs776130476, COSV100239771, COSV61319452; called by muse, mutect2, varscan2
- TRAPPC12 | c.245C>T p.A82V | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.003); catalogued as rs749587177; called by muse, mutect2, varscan2
- TRIM46 | c.154G>A p.V52M | Missense Mutation (SNP) | VAF 47/208 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs907670977; called by muse, mutect2, varscan2
- TTC3 | c.2334del p.E779Kfs*5 | Frame Shift Del (DEL) | VAF 12/60 reads (20%) | catalogued as rs756650873; called by mutect2, varscan2
- UBE2J2 | c.305C>T p.P102L | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1214697037, COSV100231075; called by muse, mutect2, varscan2
- UBE3A | c.1990G>A p.D664N | Missense Mutation (SNP) | VAF 61/306 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as COSV51664541; called by muse, mutect2, varscan2
- UBR4 | c.9871C>T p.Q3291* | Nonsense Mutation (SNP) | VAF 42/265 reads (16%) | catalogued as rs1315673851; called by muse, mutect2, varscan2
- UGT2B17 | c.270del p.F90Lfs*2 | Frame Shift Del (DEL) | VAF 36/162 reads (22%) | catalogued as rs529223604, COSV58502874; called by mutect2, varscan2
- UQCRC2 | c.535G>A p.A179T | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.324); catalogued as rs773525083; called by muse, mutect2, varscan2
- URGCP | c.2695A>G p.I899V (on ENST00000453200 / NM_001077663.3; = p.I890V on NM_017920.4) | Missense Mutation (SNP) | VAF 46/231 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs756080025; called by muse, mutect2, varscan2
- USP5 | c.2236C>T p.R746W (on ENST00000229268 / NM_001098536.2; = p.R723W on NM_003481.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1045156691, COSV57538347; called by muse, mutect2, varscan2
- VAMP8 | c.115del p.E39Kfs*36 | Frame Shift Del (DEL) | VAF 12/63 reads (19%) | catalogued as rs774807701, COSV55705928, COSV99809221; called by mutect2, pindel, varscan2
- VANGL1 | c.635G>A p.R212Q | Missense Mutation (SNP) | VAF 16/350 reads (5%) | SIFT tolerated (0.33); PolyPhen benign (0.012); catalogued as rs1009946726, COSV59622408; called by muse, mutect2
- VPS26B | c.970C>T p.R324W | Missense Mutation (SNP) | VAF 20/201 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs773146019; called by muse, varscan2
- VSTM2L | c.172G>A p.V58M | Missense Mutation (SNP) | VAF 31/179 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs752949379; called by muse, mutect2, varscan2
- VWA7 | c.2201G>A p.G734D | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs1449982736; called by muse, mutect2, varscan2
- WDTC1 | c.868del p.E290Nfs*8 | Frame Shift Del (DEL) | VAF 16/114 reads (14%) | catalogued as rs747972901, COSV60089251; called by mutect2, varscan2
- WFDC5 | c.626T>C p.I209T | Missense Mutation (SNP) | VAF 65/368 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.158); catalogued as rs1388430493; called by muse, mutect2, varscan2
- WFIKKN2 | c.1646C>T p.S549L | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.118); catalogued as rs775664209, COSV60959646; called by muse, mutect2, varscan2
- WRAP73 | c.794C>T p.A265V | Missense Mutation (SNP) | VAF 46/258 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.021); catalogued as COSV54560235, COSV54561252; called by muse, mutect2, varscan2
- WWP2 | c.1403G>A p.R468H | Missense Mutation (SNP) | VAF 23/225 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.749); catalogued as rs759088222, COSV63128207; called by muse, mutect2, varscan2
- ZAN | c.240del p.Y81Tfs*96 | Frame Shift Del (DEL) | VAF 36/232 reads (16%) | catalogued as rs773398085, COSV61809202; called by mutect2, pindel, varscan2
- ZC3H13 | c.785G>A p.R262H | Missense Mutation (SNP) | VAF 25/152 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV99668017; called by muse, mutect2, varscan2
- ZC3H4 | c.943C>T p.R315C | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs772964263; called by muse, mutect2, varscan2
- ZC3H6 | c.1760A>G p.N587S | Missense Mutation (SNP) | VAF 32/235 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1160573245; called by muse, mutect2, varscan2
- ZNF142 | c.3755del p.G1252Dfs*20 (on ENST00000411696 / NM_001379660.1; = p.G1052Dfs*20 on NM_001105537.4 and 5 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 16/145 reads (11%) | catalogued as rs751589999; called by mutect2, pindel
- ZNF169 | c.247C>A p.L83I | Missense Mutation (SNP) | VAF 47/249 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0.057); catalogued as COSV61763273; called by muse, mutect2, varscan2
- ZNF181 | c.207dup p.L70Tfs*24 | Frame Shift Ins (INS) | VAF 15/140 reads (11%) | catalogued as rs761377914; called by mutect2, pindel, varscan2
- ZNF195 | c.701G>A p.R234H (on ENST00000399602 / NM_001130520.3; = p.R162H on NM_007152.5) | Missense Mutation (SNP) | VAF 18/135 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs376274624; called by muse, mutect2, varscan2
- ZNF213 | c.1325C>T p.A442V | Missense Mutation (SNP) | VAF 27/165 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); catalogued as COSV67727852; called by muse, mutect2, varscan2
- ZNF253 | c.342del p.G115Afs*22 | Frame Shift Del (DEL) | VAF 23/133 reads (17%) | catalogued as rs774038489; called by mutect2, pindel, varscan2
- ZNF30 | c.1840C>T p.H614Y | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57853790; called by muse, mutect2
- ZNF808 | c.913C>T p.H305Y | Missense Mutation (SNP) | VAF 46/383 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1275047364; called by muse, mutect2, varscan2
- ZRANB3 | c.2564G>A p.R855H | Missense Mutation (SNP) | VAF 29/141 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs377722888; called by muse, mutect2, varscan2
- ABCA10 | c.3131del p.N1044Ifs*13 | Frame Shift Del (DEL) | VAF 12/65 reads (18%) | called by mutect2, pindel, varscan2
- ABCA2 | c.3874G>A p.V1292M (on ENST00000614293; = p.V1262M on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- ACAD11 | c.1451G>A p.S484N | Missense Mutation (SNP) | VAF 27/148 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ACP7 | c.134C>T p.S45F | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.429); called by muse, mutect2, varscan2
- ADAMTS9 | c.298T>C p.Y100H | Missense Mutation (SNP) | VAF 26/189 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAT1 | c.743dup p.G249Wfs*2 | Frame Shift Ins (INS) | VAF 29/317 reads (9%) | called by mutect2, pindel
- ADCY2 | c.187G>A p.A63T | Missense Mutation (SNP) | VAF 34/145 reads (23%) | SIFT tolerated (0.54); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ADGRD2 | c.198del p.P67Lfs*59 | Frame Shift Del (DEL) | VAF 71/450 reads (16%) | called by mutect2, pindel, varscan2
- ADGRL4 | c.1384A>T p.I462F | Missense Mutation (SNP) | VAF 36/202 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- AEBP1 | c.1745C>A p.P582H | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- AHNAK2 | c.17070del p.K5690Nfs*13 | Frame Shift Del (DEL) | VAF 41/217 reads (19%) | called by mutect2, pindel, varscan2
- AHNAK2 | c.10200G>T p.K3400N | Missense Mutation (SNP) | VAF 84/569 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); called by muse, mutect2, varscan2
- AJUBA | c.1478G>A p.C493Y | Missense Mutation (SNP) | VAF 22/145 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ALAD | c.932-1G>T p.X311_splice | Splice Site (SNP) | VAF 18/290 reads (6%) | called by muse, mutect2
- ALDH1L2 | c.62dup p.N21Kfs*19 | Frame Shift Ins (INS) | VAF 29/166 reads (17%) | called by mutect2, pindel, varscan2
- ALPP | c.443G>A p.G148D | Missense Mutation (SNP) | VAF 26/264 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.44); called by muse, mutect2
- ANK3 | c.10967C>T p.A3656V | Missense Mutation (SNP) | VAF 32/187 reads (17%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANTXRL | c.1043G>A p.C348Y | Missense Mutation (SNP) | VAF 37/261 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- AP002495.1 | c.337G>A p.D113N (on ENST00000528511; = p.D44N on NM_001375848.1) | Missense Mutation (SNP) | VAF 29/187 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- AP1M1 | c.401A>G p.Y134C | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2
- ARHGAP23 | c.1777C>A p.L593I | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT tolerated (0.57); PolyPhen benign (0.119); called by muse, mutect2
- ARHGAP36 | c.1180G>C p.G394R | Missense Mutation (SNP) | VAF 22/200 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.211); called by muse, mutect2, varscan2
- ARHGEF19 | c.103G>A p.A35T | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- ARMH1 | c.980G>A p.R327H | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARVCF | c.32G>A p.S11N | Missense Mutation (SNP) | VAF 76/458 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- ASCL1 | c.641C>T p.S214L | Missense Mutation (SNP) | VAF 37/192 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ASPHD1 | c.143del p.G48Dfs*19 | Frame Shift Del (DEL) | VAF 6/42 reads (14%) | called by mutect2, varscan2
- ASPSCR1 | c.373A>G p.R125G | Missense Mutation (SNP) | VAF 14/222 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- ASXL3 | c.1785G>T p.Q595H | Missense Mutation (SNP) | VAF 23/269 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.921); called by muse, mutect2
- ATAT1 | c.899del p.P300Hfs*31 (on ENST00000376485; = p.P300Hfs*65 on NM_024909.4) | Frame Shift Del (DEL) | VAF 31/141 reads (22%) | called by mutect2, pindel, varscan2
- ATP1A3 | c.193-2A>G p.X65_splice (on ENST00000545399 / NM_001256214.2; = p.X52_splice on NM_152296.5) | Splice Site (SNP) | VAF 58/440 reads (13%) | called by muse, varscan2
- ATRAID | c.419C>A p.P140H (on ENST00000611786; = p.P27H on NM_016085.5) | Missense Mutation (SNP) | VAF 52/324 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- ATXN2L | c.2039G>A p.S680N | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- BCAM | c.1180C>A p.L394I | Missense Mutation (SNP) | VAF 41/205 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.287); called by muse, mutect2, varscan2
- BCDIN3D | c.776T>G p.L259R | Missense Mutation (SNP) | VAF 42/183 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BDP1 | c.7155dup p.R2386Tfs*8 | Frame Shift Ins (INS) | VAF 30/167 reads (18%) | called by mutect2, pindel, varscan2
- BSX | c.619G>A p.G207S | Missense Mutation (SNP) | VAF 38/184 reads (21%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- BTBD18 | c.794T>C p.L265P | Missense Mutation (SNP) | VAF 27/360 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2
- BTG1 | c.334T>C p.S112P | Missense Mutation (SNP) | VAF 41/248 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C12orf4 | c.1567-1G>T p.X523_splice | Splice Site (SNP) | VAF 16/76 reads (21%) | called by muse, mutect2, varscan2
- C17orf98 | c.154C>T p.R52C | Missense Mutation (SNP) | VAF 43/224 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- C21orf62 | c.259A>G p.T87A | Missense Mutation (SNP) | VAF 43/262 reads (16%) | SIFT tolerated (0.49); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CASKIN1 | c.2144del p.P715Lfs*90 | Frame Shift Del (DEL) | VAF 15/108 reads (14%) | called by mutect2, pindel, varscan2
- CBLN2 | c.265G>A p.G89S | Missense Mutation (SNP) | VAF 58/316 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- CBX8 | c.956del p.G319Afs*37 | Frame Shift Del (DEL) | VAF 20/120 reads (17%) | called by mutect2, varscan2
- CCDC115 | c.430+7G>A | Splice Region (SNP) | VAF 18/168 reads (11%) | called by muse, mutect2, varscan2
- CCDC14 | c.263C>T p.A88V (on ENST00000488653; = p.A40V on NM_022757.5) | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT tolerated (0.68); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- CCDC173 | c.1109del p.N370Tfs*5 | Frame Shift Del (DEL) | VAF 11/78 reads (14%) | called by mutect2, pindel, varscan2
- CCDC183 | c.167C>T p.A56V | Missense Mutation (SNP) | VAF 26/143 reads (18%) | SIFT tolerated (0.53); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CCDC83 | c.208T>C p.W70R | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCDC88B | c.1170G>T p.E390D | Missense Mutation (SNP) | VAF 25/151 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CD274 | c.506G>A p.S169N | Missense Mutation (SNP) | VAF 55/402 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDCA2 | c.2710G>T p.G904C | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CDHR4 | c.1532A>G p.Y511C | Missense Mutation (SNP) | VAF 34/198 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- CDK5RAP3 | c.743C>A p.S248Y | Missense Mutation (SNP) | VAF 29/242 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.571); called by muse, mutect2, varscan2
- CELSR3 | c.9187G>A p.A3063T | Missense Mutation (SNP) | VAF 58/310 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- CEP250 | c.3905C>T p.S1302F | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.387); called by muse, mutect2, varscan2
- CEP295NL | c.434C>T p.A145V | Missense Mutation (SNP) | VAF 15/192 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.659); called by muse, mutect2
- CEP57 | c.202G>A p.A68T | Missense Mutation (SNP) | VAF 36/275 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); called by muse, mutect2, varscan2
- CHRNA7 | c.895A>G p.S299G | Missense Mutation (SNP) | VAF 27/122 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.685); called by muse, mutect2, varscan2
- CKAP5 | c.2728A>G p.N910D | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- COL11A2 | c.833C>A p.P278H | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- COL4A2 | c.4762A>G p.S1588G | Missense Mutation (SNP) | VAF 88/679 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- COL7A1 | c.4852C>A p.P1618T | Missense Mutation (SNP) | VAF 32/232 reads (14%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- COPS7A | c.655del p.T219Pfs*21 | Frame Shift Del (DEL) | VAF 12/128 reads (9%) | called by mutect2, pindel
- CR2 | c.1325G>A p.G442D | Missense Mutation (SNP) | VAF 80/474 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CROCC2 | c.4715C>T p.A1572V | Missense Mutation (SNP) | VAF 24/180 reads (13%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- CSPG4 | c.6160C>T p.P2054S | Missense Mutation (SNP) | VAF 61/395 reads (15%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- CTSO | c.591del p.F197Lfs*46 | Frame Shift Del (DEL) | VAF 32/202 reads (16%) | called by mutect2, pindel, varscan2
- CUL5 | c.2261A>C p.K754T | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CYFIP2 | c.2660G>A p.R887H (on ENST00000616178 / NM_001291722.2; = p.R862H on NM_014376.4) | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); called by muse, mutect2
- CYSLTR2 | c.193C>T p.Q65* | Nonsense Mutation (SNP) | VAF 20/420 reads (5%) | called by muse, mutect2
- DACH2 | c.214G>A p.D72N | Missense Mutation (SNP) | VAF 67/364 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- DBI | c.209C>T p.A70V (on ENST00000355857 / NM_001079862.3; = p.A87V on NM_020548.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/177 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- DCAF12L2 | c.40C>T p.P14S | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DCBLD2 | c.935C>T p.S312F | Missense Mutation (SNP) | VAF 38/255 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DCC | c.2599A>C p.N867H | Missense Mutation (SNP) | VAF 71/435 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- DCP1B | c.674A>G p.H225R | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by muse, varscan2
- DCUN1D3 | c.589C>T p.Q197* | Nonsense Mutation (SNP) | VAF 78/476 reads (16%) | called by muse, mutect2, varscan2
- DDB1 | c.29A>T p.Q10L | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.515); called by muse, mutect2
- DHX16 | c.3097del p.I1033* | Frame Shift Del (DEL) | VAF 10/68 reads (15%) | called by pindel, varscan2
- DISP3 | c.3689G>A p.G1230D | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- DMRT2 | c.490G>A p.A164T | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAH10 | c.8899C>T p.Q2967* (on ENST00000409039; = p.Q2906* on NM_207437.3) | Nonsense Mutation (SNP) | VAF 92/545 reads (17%) | called by muse, mutect2, varscan2
- DNAH8 | c.5222C>T p.T1741I | Missense Mutation (SNP) | VAF 38/251 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- DNAH9 | c.6820G>A p.A2274T | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DNAJC14 | c.1435del p.R479Gfs*27 | Frame Shift Del (DEL) | VAF 18/125 reads (14%) | called by mutect2, pindel, varscan2
- DQX1 | c.938A>C p.E313A | Missense Mutation (SNP) | VAF 35/342 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- DUOX1 | c.1829T>C p.L610P | Missense Mutation (SNP) | VAF 26/134 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- EHBP1L1 | c.3523G>A p.A1175T | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.035); called by muse, varscan2
- EMC1 | c.240G>T p.K80N | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- ENC1 | c.1250A>G p.Y417C | Missense Mutation (SNP) | VAF 36/483 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ENDOV | c.813del p.G273Efs*29 | Frame Shift Del (DEL) | VAF 16/116 reads (14%) | called by mutect2, pindel, varscan2
- ENO4 | c.709A>G p.M237V (on ENST00000622726; = p.M236V on NM_001242699.2) | Missense Mutation (SNP) | VAF 17/146 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.389); called by muse, mutect2, varscan2
- EPC1 | c.543G>C p.K181N | Missense Mutation (SNP) | VAF 30/180 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- EPPK1 | c.6044del p.G2015Vfs*36 | Frame Shift Del (DEL) | VAF 24/197 reads (12%) | called by mutect2, pindel, varscan2
- ERC1 | c.1649A>G p.E550G (on ENST00000360905 / NM_178040.4; = p.E522G on NM_178039.4) | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- ERICH1 | c.487del p.R163Gfs*3 | Frame Shift Del (DEL) | VAF 41/235 reads (17%) | called by mutect2, varscan2
- ESCO2 | c.376dup p.M126Nfs*22 | Frame Shift Ins (INS) | VAF 27/238 reads (11%) | called by mutect2, pindel, varscan2
- ESRRA | c.232C>A p.L78I | Missense Mutation (SNP) | VAF 29/129 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- FABP4 | c.136A>G p.N46D | Missense Mutation (SNP) | VAF 15/238 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- FAM110A | c.413del p.P138Qfs*54 | Frame Shift Del (DEL) | VAF 8/56 reads (14%) | called by pindel, varscan2
- FAM200B | c.782dup p.L261Ffs*25 | Frame Shift Ins (INS) | VAF 26/226 reads (12%) | called by mutect2, pindel, varscan2
- FAM50B | c.682C>T p.R228C | Missense Mutation (SNP) | VAF 89/498 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- FARSA | c.575T>C p.L192P | Missense Mutation (SNP) | VAF 28/191 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FBXO39 | c.1094G>A p.C365Y | Missense Mutation (SNP) | VAF 22/125 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- FBXO48 | c.439del p.E147Kfs*3 | Frame Shift Del (DEL) | VAF 11/64 reads (17%) | called by mutect2, pindel, varscan2
- FGFR2 | c.1270del p.L424Cfs*5 | Frame Shift Del (DEL) | VAF 25/151 reads (17%) | called by mutect2, pindel, varscan2
- FOS | c.412_416del p.E138Kfs*9 | Frame Shift Del (DEL) | VAF 11/92 reads (12%) | called by mutect2, pindel, varscan2
- FREM3 | c.5069C>T p.A1690V | Missense Mutation (SNP) | VAF 23/214 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.182); called by muse, mutect2, varscan2
- FREM3 | c.3641A>C p.Q1214P | Missense Mutation (SNP) | VAF 59/323 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FRY | c.8568C>A p.S2856R | Missense Mutation (SNP) | VAF 46/340 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.005); called by mutect2, varscan2
- FSIP2 | c.1124A>C p.N375T | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.007); called by muse, mutect2
- FSIP2 | c.10165del p.I3389Sfs*25 | Frame Shift Del (DEL) | VAF 11/82 reads (13%) | called by mutect2, pindel, varscan2
- FSIP2 | c.17199del p.V5734Yfs*24 | Frame Shift Del (DEL) | VAF 14/90 reads (16%) | called by mutect2, varscan2
- GARNL3 | c.311del p.L104* | Frame Shift Del (DEL) | VAF 13/83 reads (16%) | called by mutect2, pindel, varscan2
- GAS2L3 | c.2013del p.K671Nfs*16 | Frame Shift Del (DEL) | VAF 8/58 reads (14%) | called by mutect2, pindel, varscan2
- GDE1 | c.169C>A p.Q57K | Missense Mutation (SNP) | VAF 30/273 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- GJA1 | c.1036A>G p.K346E | Missense Mutation (SNP) | VAF 54/327 reads (17%) | SIFT tolerated (0.75); PolyPhen benign (0.322); called by muse, mutect2, varscan2
- GJA9 | c.769G>A p.A257T | Missense Mutation (SNP) | VAF 22/151 reads (15%) | SIFT tolerated (0.56); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GNAS | c.784A>G p.S262G | Missense Mutation (SNP) | VAF 54/862 reads (6%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); called by muse, mutect2
- GNAT3 | c.1053T>A p.C351* | Nonsense Mutation (SNP) | VAF 13/54 reads (24%) | called by muse, mutect2, varscan2
- GPATCH8 | c.3314A>G p.K1105R | Missense Mutation (SNP) | VAF 25/138 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- GRIA1 | c.2318del p.L773Wfs*4 | Frame Shift Del (DEL) | VAF 30/166 reads (18%) | called by mutect2, pindel, varscan2
- GRIA4 | c.1918G>T p.A640S | Missense Mutation (SNP) | VAF 34/234 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by mutect2, varscan2
- GRM7 | c.1149del p.E384Kfs*28 | Frame Shift Del (DEL) | VAF 32/152 reads (21%) | called by mutect2, pindel, varscan2
- GSX1 | c.128C>T p.S43L | Missense Mutation (SNP) | VAF 44/263 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- GTF3C2 | c.747dup p.L250Sfs*4 | Frame Shift Ins (INS) | VAF 24/244 reads (10%) | called by mutect2, pindel, varscan2
- HELZ2 | c.3548C>T p.P1183L (on ENST00000467148 / NM_001037335.2; = p.P614L on NM_033405.3) | Missense Mutation (SNP) | VAF 16/414 reads (4%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2
- HIP1R | c.640G>C p.A214P | Missense Mutation (SNP) | VAF 21/181 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- HLX | c.275del p.P92Rfs*105 | Frame Shift Del (DEL) | VAF 29/116 reads (25%) | called by mutect2, pindel, varscan2
- HMCN2 | c.1212G>T p.K404N | Missense Mutation (SNP) | VAF 46/268 reads (17%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.559); called by muse, mutect2, varscan2
- HOXD8 | c.761del p.K254Rfs*15 | Frame Shift Del (DEL) | VAF 11/123 reads (9%) | called by mutect2, pindel
- HPR | c.893dup p.S299Qfs*22 | Frame Shift Ins (INS) | VAF 45/317 reads (14%) | called by mutect2, pindel, varscan2
- HSF1 | c.1036A>G p.T346A | Missense Mutation (SNP) | VAF 61/452 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- HSPA2 | c.542C>T p.A181V | Missense Mutation (SNP) | VAF 44/284 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.922); called by muse, varscan2
- HSPA8 | c.1747A>G p.K583E | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ICE1 | c.6637C>T p.Q2213* | Nonsense Mutation (SNP) | VAF 20/152 reads (13%) | called by muse, mutect2, varscan2
- IGDCC4 | c.1816G>A p.A606T | Missense Mutation (SNP) | VAF 22/166 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- INSYN2A | c.406T>G p.F136V | Missense Mutation (SNP) | VAF 89/539 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- IQSEC2 | c.854dup p.A286Cfs*39 (on ENST00000642864 / NM_001111125.3; = p.A81Cfs*39 on NM_015075.2) | Frame Shift Ins (INS) | VAF 22/172 reads (13%) | called by mutect2, pindel, varscan2
- IRAK1 | c.1237-1G>T p.X413_splice | Splice Site (SNP) | VAF 28/181 reads (15%) | called by muse, mutect2, varscan2
- ISCA1 | c.289A>C p.T97P | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ITIH6 | c.3507G>T p.E1169D | Missense Mutation (SNP) | VAF 52/285 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.667); called by muse, mutect2, varscan2
- ITIH6 | c.16T>C p.Y6H | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.135); called by muse, mutect2
- ITPKA | c.941G>A p.R314H | Missense Mutation (SNP) | VAF 62/326 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ITPRIPL2 | c.922C>T p.R308C | Missense Mutation (SNP) | VAF 62/377 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KAT8 | c.571G>A p.A191T | Missense Mutation (SNP) | VAF 34/234 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KCNA3 | c.229G>A p.G77S | Missense Mutation (SNP) | VAF 26/149 reads (17%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- KCNMA1 | c.3638C>G p.A1213G (on ENST00000286628 / NM_001161352.2; = p.A1155G on NM_002247.4) | Missense Mutation (SNP) | VAF 51/524 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.15); called by muse, mutect2
- KCTD1 | c.41T>C p.L14P | Missense Mutation (SNP) | VAF 17/155 reads (11%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- KHK | c.565-8G>A | Splice Region (SNP) | VAF 46/379 reads (12%) | called by muse, mutect2, varscan2
- KIF11 | c.2990T>C p.V997A | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2
- KIFC1 | c.1235C>A p.T412K | Missense Mutation (SNP) | VAF 28/216 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KLF10 | c.109del p.S37Vfs*6 | Frame Shift Del (DEL) | VAF 23/119 reads (19%) | called by mutect2, pindel, varscan2
- KLHDC8B | c.401del p.G134Efs*56 | Frame Shift Del (DEL) | VAF 21/101 reads (21%) | called by mutect2, pindel, varscan2
- KMT2A | c.9515G>A p.S3172N | Missense Mutation (SNP) | VAF 48/305 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- KMT2D | c.7548del p.N2517Ifs*26 | Frame Shift Del (DEL) | VAF 41/200 reads (21%) | called by mutect2, pindel, varscan2
- KMT2D | c.6946C>A p.L2316M | Missense Mutation (SNP) | VAF 63/290 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- LETM1 | c.2164_2166del p.E722del | In Frame Del (DEL) | VAF 52/240 reads (22%) | called by pindel, varscan2
- LNPEP | c.2435G>A p.G812D | Missense Mutation (SNP) | VAF 12/147 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.74); called by muse, mutect2
- LPCAT3 | c.815A>T p.Y272F | Missense Mutation (SNP) | VAF 37/193 reads (19%) | SIFT tolerated (0.49); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- LRRC10B | c.847G>A p.A283T | Missense Mutation (SNP) | VAF 17/137 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- LTA4H | c.64C>T p.R22C | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- LTBP3 | c.1784dup p.D596* | Frame Shift Ins (INS) | VAF 109/644 reads (17%) | called by mutect2, pindel, varscan2
- LTBP3 | c.635T>C p.L212P | Missense Mutation (SNP) | VAF 14/359 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); called by muse, mutect2
- LURAP1L | c.235T>C p.S79P | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.653); called by muse, mutect2, varscan2
- MAGEL2 | c.2830A>T p.S944C | Missense Mutation (SNP) | VAF 57/335 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.789); called by muse, mutect2, varscan2
- MAML2 | c.1105T>G p.S369A | Missense Mutation (SNP) | VAF 21/158 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- MAP11 | c.622G>A p.A208T | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAP1A | c.7499del p.P2500Lfs*93 | Frame Shift Del (DEL) | VAF 27/179 reads (15%) | called by mutect2, pindel, varscan2
- MARF1 | c.2285A>G p.N762S | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT tolerated (0.99); PolyPhen benign (0.007); called by muse, mutect2
- MAST1 | c.1211del p.K404Rfs*7 | Frame Shift Del (DEL) | VAF 39/334 reads (12%) | called by mutect2, pindel, varscan2
- MAST1 | c.3212C>T p.A1071V | Missense Mutation (SNP) | VAF 16/142 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.199); called by muse, mutect2
- MAST2 | c.2178del p.F726Lfs*12 | Frame Shift Del (DEL) | VAF 11/83 reads (13%) | called by mutect2, pindel, varscan2
- MDN1 | c.8124G>T p.M2708I | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2
- MEIOC | c.2612G>T p.G871V | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MICAL3 | c.4890del p.R1631Gfs*33 | Frame Shift Del (DEL) | VAF 9/78 reads (12%) | called by mutect2, pindel
- MIDEAS | c.2440C>G p.P814A | Missense Mutation (SNP) | VAF 36/235 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- MLH3 | c.1685G>A p.C562Y | Missense Mutation (SNP) | VAF 14/196 reads (7%) | SIFT tolerated (0.5); PolyPhen benign (0.003); called by muse, mutect2
- MOSPD2 | c.938T>G p.V313G | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, varscan2
- MRPL55 | c.346G>A p.V116M | Missense Mutation (SNP) | VAF 30/190 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.228); called by muse, mutect2, varscan2
- MS4A2 | c.189A>G p.V63= | Splice Region (SNP) | VAF 46/324 reads (14%) | called by muse, mutect2, varscan2
- MTG1 | c.986del p.P329Rfs*28 | Frame Shift Del (DEL) | VAF 24/134 reads (18%) | called by mutect2, pindel, varscan2
- MUC16 | c.33722A>G p.H11241R | Missense Mutation (SNP) | VAF 24/244 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- MYBPC1 | c.2742A>C p.K914N (on ENST00000550270 / NM_206820.2; = p.K921N on NM_002465.4) | Missense Mutation (SNP) | VAF 19/313 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.744); called by muse, mutect2
- MYH15 | c.1339A>G p.M447V | Missense Mutation (SNP) | VAF 31/145 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.568); called by muse, mutect2, varscan2
- MYO19 | c.1649C>A p.P550H | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.716); called by muse, mutect2
- NACAD | c.1540A>C p.T514P | Missense Mutation (SNP) | VAF 20/260 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2
- NBPF14 | c.8644del p.R2882Efs*32 | Frame Shift Del (DEL) | VAF 14/148 reads (9%) | called by mutect2, pindel, varscan2
- NDST2 | c.572del p.L191Yfs*12 | Frame Shift Del (DEL) | VAF 31/141 reads (22%) | called by mutect2, pindel, varscan2
- NEPRO | c.975+8T>C | Splice Region (SNP) | VAF 10/58 reads (17%) | called by muse, varscan2
- NETO2 | c.962del p.N321Ifs*47 | Frame Shift Del (DEL) | VAF 27/205 reads (13%) | called by mutect2, pindel, varscan2
- NOTCH2 | c.1091G>A p.C364Y | Missense Mutation (SNP) | VAF 37/523 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- NOTUM | c.1457G>T p.S486I | Missense Mutation (SNP) | VAF 52/218 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.095); called by mutect2, varscan2
- NRG2 | c.519del p.L174Cfs*6 | Frame Shift Del (DEL) | VAF 39/228 reads (17%) | called by mutect2, pindel, varscan2
- NUP214 | c.733G>T p.D245Y | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NUP85 | c.1261del p.V421Sfs*24 | Frame Shift Del (DEL) | VAF 12/97 reads (12%) | called by mutect2, pindel, varscan2
- NUTM1 | c.1138G>T p.G380W | Missense Mutation (SNP) | VAF 37/236 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by mutect2, varscan2
- NUTM2D | c.1294G>A p.A432T | Missense Mutation (SNP) | VAF 34/422 reads (8%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.783); called by muse, varscan2
- NYAP2 | c.945del p.K316Rfs*57 | Frame Shift Del (DEL) | VAF 15/102 reads (15%) | called by mutect2, pindel, varscan2
- OCIAD1 | c.696del p.E233Kfs*4 | Frame Shift Del (DEL) | VAF 11/32 reads (34%) | called by mutect2, pindel, varscan2
- OPA1 | c.1038T>G p.V346= (on ENST00000361510 / NM_130837.3; = p.V291= on NM_015560.3) | Splice Region (SNP) | VAF 22/151 reads (15%) | called by muse, mutect2, varscan2
- OR14C36 | c.922dup p.Y308Lfs*? | Frame Shift Ins (INS) | VAF 6/47 reads (13%) | called by pindel, varscan2
- OR2T5 | c.159A>G p.I53M | Missense Mutation (SNP) | VAF 78/522 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- OR2W3 | c.125A>C p.N42T | Missense Mutation (SNP) | VAF 27/138 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- OR4A47 | c.839T>C p.L280P | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.059); called by mutect2, varscan2
- OR51Q1 | c.680T>A p.I227N | Missense Mutation (SNP) | VAF 25/230 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2
- OR7G1 | c.199T>C p.S67P | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OSBPL3 | c.1735dup p.L579Pfs*18 | Frame Shift Ins (INS) | VAF 14/84 reads (17%) | called by mutect2, pindel, varscan2
- P2RX6 | c.191A>G p.Y64C | Missense Mutation (SNP) | VAF 18/162 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PALLD | c.2172G>T p.Q724H | Missense Mutation (SNP) | VAF 49/306 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PAX3 | c.1438dup p.*480Lfs*21 | Frame Shift Ins (INS) | VAF 25/177 reads (14%) | called by mutect2, pindel, varscan2
- PCDHB11 | c.1837G>A p.G613R | Missense Mutation (SNP) | VAF 71/810 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PCDHB3 | c.29G>A p.R10K | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PCDHGB3 | c.797C>T p.A266V | Missense Mutation (SNP) | VAF 57/303 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCLO | c.82G>A p.G28R | Missense Mutation (SNP) | VAF 28/438 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.959); called by muse, mutect2
- PDCD6 | c.36del p.G13Afs*30 | Frame Shift Del (DEL) | VAF 11/71 reads (15%) | called by mutect2, pindel, varscan2
- PDE12 | c.308G>A p.S103N | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- PEG3 | c.2995A>G p.S999G | Missense Mutation (SNP) | VAF 42/217 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- PITX3 | c.759dup p.Y254Lfs*8 | Frame Shift Ins (INS) | VAF 23/149 reads (15%) | called by mutect2, pindel, varscan2
- PKDREJ | c.6505G>A p.A2169T | Missense Mutation (SNP) | VAF 44/248 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- PLA1A | c.1298T>C p.V433A | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.024); called by muse, mutect2
- PLAG1 | c.551dup p.H185Afs*7 | Frame Shift Ins (INS) | VAF 42/362 reads (12%) | called by mutect2, varscan2
- PLEKHG4B | c.1768C>T p.Q590* (on ENST00000283426; = p.Q946* on NM_052909.5) | Nonsense Mutation (SNP) | VAF 14/73 reads (19%) | called by muse, mutect2, varscan2
- PLK5 | c.327C>A p.P109= | Splice Region (SNP) | VAF 18/94 reads (19%) | called by muse, mutect2
- PNPT1 | c.890C>T p.A297V | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- POLRMT | c.2399T>C p.M800T | Missense Mutation (SNP) | VAF 30/490 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2
- PPARGC1B | c.1003G>T p.A335S | Missense Mutation (SNP) | VAF 29/192 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- PPEF1 | c.926T>C p.L309P | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- PPP1R37 | c.1597C>T p.P533S | Missense Mutation (SNP) | VAF 27/128 reads (21%) | SIFT tolerated, low confidence (0.22); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- PPP2R2B | c.274dup p.I92Nfs*3 (on ENST00000394409; = p.I158Nfs*3 on NM_181674.2) | Frame Shift Ins (INS) | VAF 19/118 reads (16%) | called by mutect2, pindel, varscan2
- PPRC1 | c.2804C>T p.P935L | Missense Mutation (SNP) | VAF 15/151 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.386); called by muse, mutect2, varscan2
- PRG4 | c.2798C>T p.A933V | Missense Mutation (SNP) | VAF 37/281 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PRKDC | c.8110del p.R2704Gfs*13 | Frame Shift Del (DEL) | VAF 22/156 reads (14%) | called by mutect2, pindel, varscan2
- PROB1 | c.2022del p.A675Pfs*73 | Frame Shift Del (DEL) | VAF 15/102 reads (15%) | called by mutect2, varscan2
- PRR14L | c.4234C>T p.H1412Y | Missense Mutation (SNP) | VAF 36/188 reads (19%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.693); called by muse, mutect2, varscan2
- PSG5 | c.805G>A p.A269T | Missense Mutation (SNP) | VAF 42/281 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.31); called by muse, mutect2, varscan2
- PYCR3 | c.640C>T p.L214= | Splice Region (SNP) | VAF 20/190 reads (11%) | called by muse, mutect2
- R3HDM2 | c.2015del p.P672Lfs*34 | Frame Shift Del (DEL) | VAF 16/112 reads (14%) | called by mutect2, pindel, varscan2
- RAB35 | c.544C>T p.Q182* | Nonsense Mutation (SNP) | VAF 24/232 reads (10%) | called by muse, mutect2
- RABL2B | c.667G>C p.A223P | Missense Mutation (SNP) | VAF 48/270 reads (18%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.013); called by mutect2, varscan2
- RAI14 | c.208A>G p.R70G | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.657); called by muse, mutect2, varscan2
- RALGAPB | c.1142del p.P381Hfs*11 | Frame Shift Del (DEL) | VAF 8/66 reads (12%) | called by mutect2, pindel, varscan2
- RASGRP2 | c.368G>A p.S123N | Missense Mutation (SNP) | VAF 41/268 reads (15%) | SIFT tolerated (0.66); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- RBPJL | c.443G>T p.R148M | Missense Mutation (SNP) | VAF 28/157 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- RBPMS | c.518T>C p.L173P | Missense Mutation (SNP) | VAF 91/694 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- RCC1L | c.509G>A p.R170K | Missense Mutation (SNP) | VAF 10/192 reads (5%) | SIFT tolerated (0.79); PolyPhen benign (0); called by muse, mutect2
- RCN2 | c.428_432del p.E143Gfs*4 | Frame Shift Del (DEL) | VAF 11/85 reads (13%) | called by mutect2, pindel, varscan2
- RECQL | c.211G>T p.E71* | Nonsense Mutation (SNP) | VAF 20/58 reads (34%) | called by muse, mutect2
- RELT | c.158del p.P53Qfs*178 | Frame Shift Del (DEL) | VAF 24/161 reads (15%) | called by mutect2, pindel, varscan2
- RIBC2 | c.839G>A p.G280D | Missense Mutation (SNP) | VAF 39/292 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- RIOK1 | c.1444G>A p.V482I | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- RNF130 | c.515del p.N172Tfs*6 | Frame Shift Del (DEL) | VAF 23/199 reads (12%) | called by mutect2, pindel, varscan2
- RNF144A | c.762del p.F254Lfs*87 | Frame Shift Del (DEL) | VAF 13/122 reads (11%) | called by mutect2, pindel, varscan2
- RNF17 | c.4564G>A p.A1522T | Missense Mutation (SNP) | VAF 18/141 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.215); called by muse, mutect2, varscan2
- ROCK1 | c.932del p.N311Tfs*12 | Frame Shift Del (DEL) | VAF 8/77 reads (10%) | called by mutect2, pindel, varscan2
- RP1 | c.4941del p.P1648Lfs*62 | Frame Shift Del (DEL) | VAF 78/520 reads (15%) | called by mutect2, pindel, varscan2
- RP1L1 | c.5866C>T p.P1956S | Missense Mutation (SNP) | VAF 18/158 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.062); called by mutect2, varscan2
- RP2 | c.386del p.L129Cfs*27 | Frame Shift Del (DEL) | VAF 75/487 reads (15%) | called by mutect2, pindel, varscan2
- RPIA | c.285+2T>C p.X95_splice | Splice Site (SNP) | VAF 18/263 reads (7%) | called by muse, mutect2
- RPS6KA5 | c.1736T>C p.L579P | Missense Mutation (SNP) | VAF 20/154 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RPS6KC1 | c.1307C>A p.P436H | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.155); called by mutect2, varscan2
- RXRA | c.370T>C p.S124P | Missense Mutation (SNP) | VAF 21/151 reads (14%) | SIFT tolerated (0.45); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SACS | c.10203dup p.D3402Rfs*2 | Frame Shift Ins (INS) | VAF 50/414 reads (12%) | called by mutect2, pindel, varscan2
- SBNO2 | c.3469C>T p.Q1157* | Nonsense Mutation (SNP) | VAF 20/96 reads (21%) | called by muse, mutect2, varscan2
- SCAPER | c.2646-2A>G p.X882_splice | Splice Site (SNP) | VAF 15/94 reads (16%) | called by muse, mutect2, varscan2
- SCO1 | c.686G>A p.G229D | Missense Mutation (SNP) | VAF 41/207 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SDK1 | c.6362C>T p.A2121V | Missense Mutation (SNP) | VAF 40/227 reads (18%) | SIFT tolerated (0.72); PolyPhen benign (0); called by muse, mutect2, varscan2
- SEC22C | c.421del p.I141Ffs*24 | Frame Shift Del (DEL) | VAF 26/192 reads (14%) | called by mutect2, pindel, varscan2
- SEL1L3 | c.2586-5_2586-4del | Splice Region (DEL) | VAF 15/62 reads (24%) | called by mutect2, varscan2
- SEMA3E | c.2230A>G p.M744V | Missense Mutation (SNP) | VAF 28/480 reads (6%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2
- SEMA3F | c.2168del p.P723Qfs*8 | Frame Shift Del (DEL) | VAF 26/158 reads (16%) | called by mutect2, varscan2
- SENP1 | c.154G>T p.G52* | Nonsense Mutation (SNP) | VAF 12/84 reads (14%) | called by mutect2, varscan2
- SENP6 | c.2503G>T p.A835S | Missense Mutation (SNP) | VAF 16/264 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0.183); called by muse, mutect2
- SETMAR | c.1787A>G p.Q596R | Missense Mutation (SNP) | VAF 44/198 reads (22%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- SFRP5 | c.79G>A p.A27T | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- SFTPB | c.1105A>G p.M369V | Missense Mutation (SNP) | VAF 18/231 reads (8%) | SIFT tolerated (0.39); PolyPhen benign (0.001); called by muse, mutect2
- SH3BP5L | c.1168_1170del p.S390del | In Frame Del (DEL) | VAF 24/119 reads (20%) | called by mutect2, pindel, varscan2
480 further variants in this file (87 protein-altering or splice-affecting, 247 silent, 146 other) are not listed here.
